Somatic mutation profile of tumor specimen 8960a27e-69d8-4ec8-a795-c6cf8a (aliquot 8960a27e-69d8-4ec8-a795-c6cf8a_D6) from CPTAC case 11CO033, project CPTAC-2 (Colon — Adenomas and Adenocarcinomas). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIA.
Specimen 8960a27e-69d8-4ec8-a795-c6cf8a: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 94dcdd4e-1169-4ba4-9118-588dcf37f126.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen d14ecda4-00aa-463e-b6a9-a8a255 (Blood Derived Normal), aliquot d14ecda4-00aa-463e-b6a9-a8a255_D1_2; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e5e68c9c-c653-4a1c-88b6-83895f2ab2af

The open-access MAF lists 2,366 somatic variants for this specimen: 1,583 protein-altering or splice-affecting, 512 silent, 271 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1,164, Silent 512, Frame Shift Del 266, Intron 142, Nonsense Mutation 60, 3'UTR 44, Frame Shift Ins 37, Splice Region 29, RNA 26, 5'UTR 21, 3'Flank 21, Splice Site 18.

Variants (750 of 2,366; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA4 | c.3056C>T p.T1019M | Missense Mutation (SNP) | VAF 46/347 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201855602, CM983373; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCD1 | c.1628C>T p.P543L | Missense Mutation (SNP) | VAF 55/188 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.449); catalogued as rs1557054776, CD107886, CM000642, COSV99497521; ClinVar: pathogenic; called by muse, mutect2, varscan2
- APC | c.271del p.M91Cfs*34 | Frame Shift Del (DEL) | VAF 18/184 reads (10%) | catalogued as rs1554069710; ClinVar: pathogenic; called by mutect2, varscan2
- ATP1A2 | c.2066G>A p.R689Q | Missense Mutation (SNP) | VAF 90/650 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs28933401, CM032182, COSV63402942; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- B4GALNT1 | c.263del p.G88Afs*24 | Frame Shift Del (DEL) | VAF 21/161 reads (13%) | catalogued as rs745744124; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- B9D1 | c.466C>T p.R156W | Missense Mutation (SNP) | VAF 22/257 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs369488112, COSV52069073; ClinVar: pathogenic; called by muse, mutect2
- CA4 | c.206G>A p.R69H | Missense Mutation (SNP) | VAF 93/608 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as rs121434552, CM072913, COSV56282434, COSV99039723; ClinVar: pathogenic; called by muse, varscan2
- CDH1 | c.1137G>A p.T379= | Splice Region (SNP) | VAF 30/314 reads (10%) | catalogued as rs587783050, CS060517, COSV55733400; ClinVar: pathogenic; called by muse, mutect2
- DMBX1 | c.367C>T p.R123W | Missense Mutation (SNP) | VAF 19/148 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs730882203, CM150810; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- EP300 | c.4585C>T p.R1529* | Nonsense Mutation (SNP) | VAF 16/139 reads (12%) | catalogued as rs1569118537, CM162047, COSV54325565; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ERBB4 | c.1630C>T p.R544W | Missense Mutation (SNP) | VAF 19/258 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs267599192, COSV53516478; ClinVar: likely pathogenic; called by muse, mutect2
- ERI1 | c.627del p.V210* | Frame Shift Del (DEL) | VAF 21/103 reads (20%) | catalogued as rs1563322318; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- EYS | c.8608C>T p.R2870* (on ENST00000370621 / NM_001292009.1; = p.R2849* on NM_001142800.2) | Nonsense Mutation (SNP) | VAF 34/312 reads (11%) | catalogued as rs1326635278, COSV101011692; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- FBP1 | c.490G>A p.G164S | Missense Mutation (SNP) | VAF 31/266 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as rs121918188, CM970524; ClinVar: pathogenic; called by muse, mutect2, varscan2
- HNF1B | c.826C>T p.R276* | Nonsense Mutation (SNP) | VAF 18/92 reads (20%) | catalogued as rs121918672, CM021700, CM055552; ClinVar: pathogenic; called by muse, mutect2, varscan2
- IQSEC2 | c.848del p.G283Afs*23 (on ENST00000642864 / NM_001111125.3; = p.G78Afs*23 on NM_015075.2) | Frame Shift Del (DEL) | VAF 23/125 reads (18%) | catalogued as rs782660318, COSV64726734; ClinVar: pathogenic; called by mutect2, varscan2
- KCNT1 | c.2743G>A p.A915T (on ENST00000488444; = p.A934T on NM_020822.3) | Missense Mutation (SNP) | VAF 20/141 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.656); catalogued as rs397515403, CM129794, COSV53703025, COSV99706966; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MATN3 | c.359C>T p.T120M | Missense Mutation (SNP) | VAF 24/196 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs397515546, CM040089, COSV68100368; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MYH7 | c.2012G>A p.R671H | Missense Mutation (SNP) | VAF 39/352 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs730880883, CM1412211; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- NBN | c.1396del p.R466Gfs*18 | Frame Shift Del (DEL) | VAF 29/217 reads (13%) | catalogued as rs1349928568; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- NDUFAF6 | c.485del p.N162Ifs*27 | Frame Shift Del (DEL) | VAF 32/180 reads (18%) | catalogued as rs762093523, COSV54408680; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- NOTCH3 | c.4556T>C p.L1519P | Missense Mutation (SNP) | VAF 18/196 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs367543285, CM134991, COSV54644378; ClinVar: not provided / pathogenic; called by muse, mutect2
- PAX2 | c.76del p.V26Cfs*3 | Frame Shift Del (DEL) | VAF 12/142 reads (8%) | catalogued as rs75462234, COSV62291007; ClinVar: pathogenic; called by mutect2, pindel
- PTEN | c.968del p.N323Mfs*21 | Frame Shift Del (DEL) | VAF 26/182 reads (14%) | catalogued as rs121913291; ClinVar: likely pathogenic / pathogenic; called by pindel, varscan2
- RAD50 | c.2165del p.K722Rfs*14 | Frame Shift Del (DEL) | VAF 25/182 reads (14%) | catalogued as rs397507178, COSV54758496; ClinVar: pathogenic; called by mutect2, varscan2
- RBCK1 | c.325C>T p.R109* (on ENST00000356286 / NM_031229.4; = p.R67* on NM_006462.6) | Nonsense Mutation (SNP) | VAF 43/362 reads (12%) | catalogued as rs1568554654; ClinVar: pathogenic; called by muse, mutect2, varscan2
- RIN2 | c.1878dup p.I627Hfs*7 (on ENST00000255006 / NM_001242581.1; = p.I578Hfs*7 on NM_018993.4 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 30/220 reads (14%) | catalogued as rs759390822; ClinVar: pathogenic; called by mutect2, varscan2
- SHANK3 | c.2054G>A p.R685H | Missense Mutation (SNP) | VAF 31/220 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.139); catalogued as rs1064796528; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AATK | c.893C>T p.A298V (on ENST00000326724 / NM_001080395.3; = p.A195V on NM_004920.2) | Missense Mutation (SNP) | VAF 28/243 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1294192888; called by muse, mutect2, varscan2
- ABCA2 | c.6062G>A p.R2021H (on ENST00000614293; = p.R1991H on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 44/303 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.702); catalogued as rs747402455; called by muse, mutect2, varscan2
- ABCA6 | c.917del p.L306Yfs*7 | Frame Shift Del (DEL) | VAF 28/150 reads (19%) | catalogued as rs750282619, COSV52635694; called by mutect2, varscan2
- ABCB11 | c.3767C>T p.T1256M | Missense Mutation (SNP) | VAF 13/122 reads (11%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.882); catalogued as rs763244136; called by muse, mutect2, varscan2
- ABCG8 | c.1505C>T p.P502L | Missense Mutation (SNP) | VAF 27/294 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs761153163, COSV55393664; called by muse, mutect2
- ABR | c.881C>T p.T294M (on ENST00000302538 / NM_021962.5; = p.T257M on NM_001092.5) | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.629); catalogued as COSV99348953; called by muse, mutect2, varscan2
- ABT1 | c.590C>T p.A197V | Missense Mutation (SNP) | VAF 36/277 reads (13%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.503); catalogued as COSV51292373; called by muse, mutect2, varscan2
- AC004832.3 | c.821G>A p.R274H | Missense Mutation (SNP) | VAF 84/792 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs147279727; called by muse, varscan2
- AC092143.1 | c.1507C>T p.R503C | Missense Mutation (SNP) | VAF 88/800 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); catalogued as COSV59248295; called by mutect2, varscan2
- ACAA1 | c.1054G>A p.A352T | Missense Mutation (SNP) | VAF 18/146 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.338); catalogued as rs1259030058; called by muse, mutect2
- ACAA1 | c.499C>T p.R167C | Missense Mutation (SNP) | VAF 29/223 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.041); catalogued as rs751653410; called by muse, mutect2, varscan2
- ACACB | c.769del p.D257Ifs*17 | Frame Shift Del (DEL) | VAF 18/133 reads (14%) | catalogued as rs768607691; called by mutect2, pindel, varscan2
- ACHE | c.703G>A p.A235T | Missense Mutation (SNP) | VAF 32/321 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs765718944, COSV53814894; called by muse, mutect2
- ACOT11 | c.1075C>T p.R359C | Missense Mutation (SNP) | VAF 14/89 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs762294773; called by muse, mutect2, varscan2
- ACOT7 | c.497C>T p.S166L (on ENST00000377855 / NM_181864.3; = p.S156L on NM_007274.4) | Missense Mutation (SNP) | VAF 26/192 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1381160910; called by muse, mutect2, varscan2
- ACTA1 | c.487C>G p.H163D | Missense Mutation (SNP) | VAF 19/193 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as CM095293, COSV100796695; called by muse, mutect2
- ACVR2A | c.1310del p.K437Rfs*5 | Frame Shift Del (DEL) | VAF 12/70 reads (17%) | catalogued as rs764719749, COSV104385546; called by mutect2, varscan2
- ACVRL1 | c.169C>T p.R57W | Missense Mutation (SNP) | VAF 56/508 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.009); catalogued as rs759670132; called by muse, mutect2
- ACVRL1 | c.253G>A p.V85I | Missense Mutation (SNP) | VAF 66/567 reads (12%) | SIFT tolerated (0.39); PolyPhen benign (0.067); catalogued as rs373779426; called by muse, mutect2, varscan2
- ADAM9 | c.1787G>A p.R596Q | Missense Mutation (SNP) | VAF 32/169 reads (19%) | SIFT tolerated (0.61); PolyPhen benign (0.007); catalogued as rs138482520; called by muse, mutect2, varscan2
- ADAMTS10 | c.2434C>T p.R812C | Missense Mutation (SNP) | VAF 58/579 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); catalogued as rs1206816425, COSV54357811; called by muse, mutect2, varscan2
- ADAMTS13 | c.1225C>T p.R409W | Missense Mutation (SNP) | VAF 80/854 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs959872423, CM129656; called by muse, mutect2
- ADAMTS6 | c.2431G>A p.V811I | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated (0.41); PolyPhen benign (0.065); catalogued as rs757808944; called by muse, mutect2, varscan2
- ADAMTS8 | c.960G>T p.Q320H | Missense Mutation (SNP) | VAF 22/222 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.139); catalogued as rs769156479; called by muse, mutect2
- ADAMTSL2 | c.2023G>A p.E675K | Missense Mutation (SNP) | VAF 50/590 reads (8%) | SIFT tolerated (0.85); PolyPhen benign (0.22); catalogued as rs1477694170; called by muse, mutect2
- ADCY8 | c.1541C>T p.S514L | Missense Mutation (SNP) | VAF 26/135 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs763633456, COSV53917295; called by muse, mutect2, varscan2
- ADCY8 | c.941C>T p.A314V | Missense Mutation (SNP) | VAF 26/180 reads (14%) | SIFT tolerated (0.52); PolyPhen benign (0.009); catalogued as rs184754999, COSV53910891; called by muse, mutect2, varscan2
- ADCY8 | c.268C>T p.P90S | Missense Mutation (SNP) | VAF 15/277 reads (5%) | SIFT tolerated, low confidence (0.67); PolyPhen possibly damaging (0.641); catalogued as rs1318110781; called by muse, mutect2
- ADGRB2 | c.1823G>A p.R608H | Missense Mutation (SNP) | VAF 16/110 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1180693274, COSV57080656; called by muse, mutect2, varscan2
- ADGRF4 | c.245del p.K82Sfs*29 | Frame Shift Del (DEL) | VAF 8/58 reads (14%) | catalogued as rs764604854; called by pindel, varscan2
- AFAP1L1 | c.695G>A p.R232H | Missense Mutation (SNP) | VAF 42/502 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs370079883; called by muse, mutect2
- AFDN | c.4834C>T p.R1612W (on ENST00000447894 / NM_001366320.1; = p.R1610W on NM_001040000.3) | Missense Mutation (SNP) | VAF 15/121 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as rs765756915; called by muse, mutect2, varscan2
- AGPAT1 | c.668G>A p.R223H | Missense Mutation (SNP) | VAF 26/244 reads (11%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.731); catalogued as rs1174931612, COSV61247485; called by muse, mutect2, varscan2
- AGTR1 | c.418C>T p.R140C | Missense Mutation (SNP) | VAF 25/194 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763952495, COSV62557123; called by muse, mutect2, varscan2
- AHI1 | c.3389A>G p.E1130G | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as COSV55628251; called by muse, mutect2, varscan2
- AKR1C1 | c.772C>T p.R258C | Missense Mutation (SNP) | VAF 18/518 reads (3%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.977); catalogued as rs570906796; called by muse, mutect2
- AKT2 | c.153del p.L52* | Frame Shift Del (DEL) | VAF 53/477 reads (11%) | catalogued as COSV100251670; called by mutect2, pindel, varscan2
- ALDH2 | c.1327G>A p.G443R | Missense Mutation (SNP) | VAF 25/155 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as rs867446901; called by muse, mutect2, varscan2
- ALKBH2 | c.695C>T p.T232M | Missense Mutation (SNP) | VAF 19/165 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.524); catalogued as rs141848154; called by muse, mutect2, varscan2
- ALS2CL | c.988del p.A330Lfs*44 | Frame Shift Del (DEL) | VAF 11/98 reads (11%) | catalogued as rs746210461; called by mutect2, varscan2
- ANAPC1 | c.3143G>A p.R1048H | Missense Mutation (SNP) | VAF 38/338 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as rs1285246821; called by muse, mutect2, varscan2
- ANK3 | c.6652G>A p.A2218T | Missense Mutation (SNP) | VAF 24/262 reads (9%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.255); catalogued as COSV55043939; called by muse, mutect2
- ANKRD11 | c.6959C>T p.T2320M | Missense Mutation (SNP) | VAF 33/343 reads (10%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.165); catalogued as rs1404340796; called by muse, mutect2
- ANKRD12 | c.815G>A p.R272H | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as rs757301244, COSV50821147; called by muse, mutect2, varscan2
- ANKRD30A | c.3482C>T p.A1161V (on ENST00000611781; = p.A1105V on NM_052997.2) | Missense Mutation (SNP) | VAF 16/136 reads (12%) | SIFT tolerated (0.24); PolyPhen benign (0.006); catalogued as COSV64606588; called by muse, mutect2, varscan2
- ANO1 | c.1433G>A p.R478Q | Missense Mutation (SNP) | VAF 15/92 reads (16%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as rs765340126; called by muse, mutect2, varscan2
- ANO1 | c.1600G>A p.V534I | Missense Mutation (SNP) | VAF 28/226 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV60287566; called by muse, mutect2
- AP1B1 | c.910C>T p.R304C | Missense Mutation (SNP) | VAF 17/120 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1043625113, COSV58019828; called by muse, mutect2, varscan2
- APBB2 | c.1978A>G p.M660V (on ENST00000295974 / NM_001166050.2; = p.M661V on NM_004307.2) | Missense Mutation (SNP) | VAF 11/105 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs766403895; called by muse, mutect2, varscan2
- APCDD1 | c.571C>T p.R191* | Nonsense Mutation (SNP) | VAF 36/363 reads (10%) | catalogued as rs766947286, COSV62372295; called by muse, mutect2, varscan2
- APIP | c.283del p.S95Afs*8 | Frame Shift Del (DEL) | VAF 6/35 reads (17%) | catalogued as rs546686089; called by mutect2, varscan2
- APOA5 | c.317G>A p.R106H | Missense Mutation (SNP) | VAF 51/358 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.168); catalogued as rs1434092204, COSV57063116; called by muse, mutect2, varscan2
- APOBR | c.1913G>A p.R638Q (on ENST00000431282; = p.R647Q on NM_018690.4) | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT tolerated (0.38); PolyPhen benign (0.025); catalogued as rs565646942, COSV60491308; called by muse, mutect2, varscan2
- APOE | c.550del p.A184Pfs*67 | Frame Shift Del (DEL) | VAF 12/90 reads (13%) | catalogued as COSV52985188; called by mutect2, pindel, varscan2
- APOF | c.719C>T p.A240V | Missense Mutation (SNP) | VAF 25/294 reads (9%) | SIFT tolerated (0.58); PolyPhen benign (0.001); catalogued as rs578174811; called by muse, mutect2
- ARAP1 | c.1109G>A p.R370H (on ENST00000393609 / NM_001040118.2; = p.R125H on NM_015242.4) | Missense Mutation (SNP) | VAF 16/112 reads (14%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.97); catalogued as rs755884731; called by muse, varscan2
- ARAP3 | c.1796G>A p.R599H | Missense Mutation (SNP) | VAF 25/194 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.751); catalogued as rs149532200; called by muse, mutect2, varscan2
- ARFGEF3 | c.3278G>A p.R1093Q | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as rs1027047587; called by muse, mutect2, varscan2
- ARFGEF3 | c.6263G>A p.R2088Q | Missense Mutation (SNP) | VAF 20/126 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); catalogued as COSV52451177; called by muse, mutect2, varscan2
- ARHGAP23 | c.1826G>A p.R609H | Missense Mutation (SNP) | VAF 14/106 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.899); catalogued as rs938457386; called by muse, mutect2, varscan2
- ARHGAP23 | c.3161G>A p.R1054Q | Missense Mutation (SNP) | VAF 14/182 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as rs142374860; called by muse, mutect2
- ARHGAP45 | c.761C>T p.T254M | Missense Mutation (SNP) | VAF 38/287 reads (13%) | SIFT tolerated (0.25); PolyPhen benign (0.107); catalogued as rs779422486; called by muse, mutect2, varscan2
- ARHGEF10 | c.3392C>T p.T1131M (on ENST00000398564; = p.T1106M on NM_014629.4) | Missense Mutation (SNP) | VAF 133/674 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.795); catalogued as rs367794138; called by muse, mutect2, varscan2
- ARL4D | c.478G>A p.A160T | Missense Mutation (SNP) | VAF 39/360 reads (11%) | SIFT tolerated (0.57); PolyPhen benign (0.066); catalogued as rs866011666; called by muse, mutect2, varscan2
- ARL6IP5 | c.296C>T p.T99M | Missense Mutation (SNP) | VAF 41/305 reads (13%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.946); catalogued as rs768102919; called by muse, mutect2, varscan2
- ARMC9 | c.1214G>A p.R405H | Missense Mutation (SNP) | VAF 11/90 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV63019624; called by muse, mutect2, varscan2
- ARVCF | c.617G>A p.R206Q | Missense Mutation (SNP) | VAF 21/158 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); catalogued as rs1352121445; called by muse, mutect2, varscan2
- ASB2 | c.886G>A p.A296T | Missense Mutation (SNP) | VAF 23/218 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs772682511, COSV60113444; called by muse, mutect2, varscan2
- ASH1L | c.7204C>T p.R2402* (on ENST00000368346 / NM_001366177.2; = p.R2397* on NM_018489.3) | Nonsense Mutation (SNP) | VAF 8/77 reads (10%) | catalogued as CM1513932; called by muse, mutect2, varscan2
- ASL | c.376C>T p.R126W | Missense Mutation (SNP) | VAF 57/377 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs201962738, CM141219, COSV100508852; called by muse, mutect2, varscan2
- ASTN1 | c.664G>A p.V222M | Missense Mutation (SNP) | VAF 55/404 reads (14%) | SIFT tolerated, low confidence (0.2); PolyPhen possibly damaging (0.674); catalogued as rs148328689, COSV56064456, COSV56089433; called by muse, mutect2, varscan2
- ASXL2 | c.3997G>A p.V1333I | Missense Mutation (SNP) | VAF 39/301 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.158); catalogued as COSV55468330; called by muse, mutect2, varscan2
- ATAD2 | c.354del p.E119Kfs*8 | Frame Shift Del (DEL) | VAF 12/51 reads (24%) | catalogued as rs746676748; called by mutect2, varscan2
- ATCAY | c.445G>A p.A149T | Missense Mutation (SNP) | VAF 14/120 reads (12%) | SIFT tolerated (0.46); PolyPhen benign (0.005); catalogued as rs199529579; called by mutect2, varscan2
- ATF7IP | c.67C>T p.R23C | Missense Mutation (SNP) | VAF 12/140 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs1369830429; called by muse, mutect2
- ATP10A | c.3749C>T p.A1250V | Missense Mutation (SNP) | VAF 14/130 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.062); catalogued as rs146387652; called by muse, mutect2, varscan2
- ATP11C | c.2443C>A p.L815M | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV100557289; called by muse, mutect2, varscan2
- ATP13A1 | c.1460C>T p.S487L | Missense Mutation (SNP) | VAF 33/293 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs1464783845, COSV52282532; called by muse, mutect2, varscan2
- ATP13A3 | c.3662C>T p.A1221V (on ENST00000645319 / NM_001367549.1; = p.A1191V on NM_024524.3) | Missense Mutation (SNP) | VAF 22/200 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.615); catalogued as rs773710020, COSV55465165; called by muse, mutect2, varscan2
- ATP1A2 | c.785G>A p.R262Q | Missense Mutation (SNP) | VAF 31/213 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.386); catalogued as rs769129830; called by muse, mutect2, varscan2
- ATP1A3 | c.767C>T p.T256M (on ENST00000545399 / NM_001256214.2; = p.T243M on NM_152296.5) | Missense Mutation (SNP) | VAF 33/229 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.723); catalogued as COSV57487559; called by muse, mutect2, varscan2
- ATP2A1 | c.2857del p.L953Cfs*3 | Frame Shift Del (DEL) | VAF 68/443 reads (15%) | catalogued as rs766340733, COSV62869135, COSV62870983; called by mutect2, pindel, varscan2
- ATP6V0A4 | c.88G>A p.G30R | Missense Mutation (SNP) | VAF 20/200 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1233261241, COSV59473427; called by muse, mutect2
- ATP6V1A | c.1802A>G p.Y601C | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.755); catalogued as rs1273155095; called by muse, mutect2, varscan2
- ATP6V1G2 | c.236G>A p.R79H | Missense Mutation (SNP) | VAF 20/142 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.734); catalogued as rs749507285; called by muse, mutect2, varscan2
- ATP7B | c.311C>T p.P104L | Missense Mutation (SNP) | VAF 49/428 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.876); catalogued as rs1252338037, COSV54437298; called by muse, mutect2, varscan2
- ATXN2L | c.1811C>T p.S604L | Missense Mutation (SNP) | VAF 35/202 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs777759993, COSV57378067; called by muse, mutect2, varscan2
- ATXN2L | c.2594C>T p.A865V | Missense Mutation (SNP) | VAF 28/266 reads (11%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.679); catalogued as rs761988132, COSV57370807; called by muse, mutect2, varscan2
- AUTS2 | c.1354G>A p.A452T | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT tolerated (0.21); PolyPhen benign (0.006); catalogued as rs749176066, COSV100719704, COSV61385358; called by muse, mutect2, varscan2
- AXL | c.874del p.H292Ifs*5 | Frame Shift Del (DEL) | VAF 15/152 reads (10%) | catalogued as rs778012871; called by mutect2, varscan2
- AZI2 | c.250G>A p.V84M | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.175); catalogued as COSV55423980; called by muse, mutect2, varscan2
- B2M | c.45_48del p.S16Afs*27 | Frame Shift Del (DEL) | VAF 38/378 reads (10%) | catalogued as COSV62562863; called by mutect2, pindel
- B3GNT4 | c.401G>A p.R134H | Missense Mutation (SNP) | VAF 28/171 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs182526849; called by muse, mutect2, varscan2
- BAHD1 | c.1310G>A p.R437H | Missense Mutation (SNP) | VAF 29/226 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.017); catalogued as rs371754615; called by muse, mutect2, varscan2
- BAIAP2 | c.397G>A p.A133T | Missense Mutation (SNP) | VAF 21/152 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.145); catalogued as rs777916497, COSV58335530; called by muse, mutect2, varscan2
- BCHE | c.1027A>C p.T343P | Missense Mutation (SNP) | VAF 15/130 reads (12%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.816); catalogued as CM025285, COSV52257903; called by muse, mutect2, varscan2
- BCL9L | c.3874G>A p.A1292T | Missense Mutation (SNP) | VAF 27/207 reads (13%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as rs771126846, COSV52684875; called by muse, mutect2, varscan2
- BCL9L | c.3380del p.P1127Hfs*21 | Frame Shift Del (DEL) | VAF 25/152 reads (16%) | catalogued as rs751794665; called by mutect2, varscan2
- BCL9L | c.1448del p.P483Rfs*19 | Frame Shift Del (DEL) | VAF 8/79 reads (10%) | catalogued as rs752970264; called by mutect2, pindel, varscan2
- BCORL1 | c.2074G>A p.E692K | Missense Mutation (SNP) | VAF 49/215 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV54391115, COSV54392951; called by muse, mutect2, varscan2
- BCORL1 | c.5042del p.P1681Qfs*20 | Frame Shift Del (DEL) | VAF 41/177 reads (23%) | catalogued as rs768244116; called by mutect2, pindel, varscan2
- BEAN1 | c.230A>G p.H77R | Missense Mutation (SNP) | VAF 26/266 reads (10%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV100227987; called by muse, mutect2
- BEST1 | c.605G>A p.R202Q | Missense Mutation (SNP) | VAF 54/458 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.659); catalogued as rs753437612; called by muse, mutect2, varscan2
- BEST3 | c.421C>T p.R141C | Missense Mutation (SNP) | VAF 18/124 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs748231464, COSV56994383; called by muse, mutect2, varscan2
- BICD2 | c.2075C>T p.T692M | Missense Mutation (SNP) | VAF 22/174 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs777172982; called by muse, mutect2, varscan2
- BICD2 | c.1349G>A p.R450H | Missense Mutation (SNP) | VAF 24/364 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.905); catalogued as rs545926410, COSV63549677; ClinVar: uncertain significance; called by muse, mutect2
- BICDL2 | c.50del p.G17Afs*34 | Frame Shift Del (DEL) | VAF 38/304 reads (13%) | catalogued as rs1567424641; called by mutect2, pindel, varscan2
- BIN1 | c.1745G>A p.G582D (on ENST00000316724 / NM_001320642.1; = p.G443D on NM_004305.4) | Missense Mutation (SNP) | VAF 32/295 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52119428; called by muse, mutect2, varscan2
- BIRC6 | c.4168C>T p.R1390C | Missense Mutation (SNP) | VAF 24/126 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs1335001376, COSV70197450; called by muse, mutect2, varscan2
- BIRC6 | c.8881T>C p.S2961P | Missense Mutation (SNP) | VAF 29/266 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.473); catalogued as COSV101429490; called by muse, mutect2, varscan2
- BMP2K | c.3056G>A p.R1019H | Missense Mutation (SNP) | VAF 30/279 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs1231973566, COSV99785204; called by muse, mutect2, varscan2
- BMPR2 | c.1748del p.N583Tfs*44 | Frame Shift Del (DEL) | VAF 22/128 reads (17%) | catalogued as rs772920507, COSV65808737; called by mutect2, pindel, varscan2
- BOC | c.2680C>T p.R894* | Nonsense Mutation (SNP) | VAF 52/428 reads (12%) | catalogued as rs1260764062; called by muse, mutect2, varscan2
- BPIFB6 | c.148G>A p.E50K | Missense Mutation (SNP) | VAF 17/147 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.066); catalogued as rs755029595, COSV99051283; called by muse, mutect2, varscan2
- BRAT1 | c.406G>A p.A136T | Missense Mutation (SNP) | VAF 9/84 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.248); catalogued as rs1562582288; ClinVar: uncertain significance; called by mutect2, varscan2
- BRD3 | c.788C>T p.S263L | Missense Mutation (SNP) | VAF 24/208 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.033); catalogued as rs201027330; called by muse, mutect2, varscan2
- BRIP1 | c.1165G>A p.V389I | Missense Mutation (SNP) | VAF 14/137 reads (10%) | SIFT tolerated (0.44); PolyPhen benign (0.149); catalogued as rs587780825; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BRWD1 | c.2615C>T p.A872V | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.051); catalogued as rs771878139; called by muse, mutect2, varscan2
- BSN | c.5128G>A p.A1710T | Missense Mutation (SNP) | VAF 47/411 reads (11%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs768573010; called by muse, mutect2, varscan2
- BTBD2 | c.778G>A p.D260N | Missense Mutation (SNP) | VAF 13/87 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs1464484738; called by muse, mutect2, varscan2
- BUB1 | c.1753C>T p.R585C | Missense Mutation (SNP) | VAF 7/97 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as rs1187464081, COSV57064044; called by muse, mutect2
- BYSL | c.1306G>A p.V436M | Missense Mutation (SNP) | VAF 12/108 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs770724028; called by muse, mutect2, varscan2
- C10orf71 | c.1167del p.E392Kfs*7 | Frame Shift Del (DEL) | VAF 17/144 reads (12%) | catalogued as rs748396302, COSV100109987; called by mutect2, pindel, varscan2
- C11orf52 | c.269G>A p.R90Q | Missense Mutation (SNP) | VAF 30/327 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs782789841, COSV53715400; called by muse, mutect2
- C15orf39 | c.574C>T p.R192W | Missense Mutation (SNP) | VAF 22/233 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.648); catalogued as rs548759069; called by muse, mutect2
- C20orf85 | c.269del p.P90Qfs*19 | Frame Shift Del (DEL) | VAF 8/76 reads (11%) | catalogued as rs777635732, COSV100959338, COSV64519981; called by mutect2, varscan2
- C2CD2L | c.427G>A p.V143I | Missense Mutation (SNP) | VAF 13/102 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs757059226, COSV60884204; called by muse, mutect2, varscan2
- C2orf16 | c.5800C>T p.R1934C | Missense Mutation (SNP) | VAF 22/180 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.57); catalogued as rs1184118126, COSV62674940; called by muse, mutect2, varscan2
- C2orf73 | c.309del p.F103Lfs*17 | Frame Shift Del (DEL) | VAF 7/66 reads (11%) | catalogued as rs747496393; called by mutect2, pindel
- C2orf78 | c.1364del p.P455Rfs*28 | Frame Shift Del (DEL) | VAF 17/175 reads (10%) | catalogued as COSV68517668; called by mutect2, pindel, varscan2
- C7orf57 | c.620del p.N207Tfs*92 | Frame Shift Del (DEL) | VAF 17/186 reads (9%) | catalogued as rs775739111; called by mutect2, pindel
- C8orf89 | c.457del p.S153Afs*16 | Frame Shift Del (DEL) | VAF 16/84 reads (19%) | catalogued as rs951061763; called by mutect2, varscan2
- CABS1 | c.382A>G p.T128A | Missense Mutation (SNP) | VAF 31/196 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1212192740; called by muse, mutect2, varscan2
- CACNA1B | c.1130G>A p.R377Q | Missense Mutation (SNP) | VAF 12/107 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs774297154; called by muse, mutect2, varscan2
- CACNA1D | c.3772G>A p.A1258T (on ENST00000350061 / NM_001128840.3; = p.A1278T on NM_000720.4) | Missense Mutation (SNP) | VAF 34/444 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs371966930; called by muse, mutect2
- CACNA1D | c.6050C>T p.P2017L (on ENST00000350061 / NM_001128840.3; = p.P2037L on NM_000720.4) | Missense Mutation (SNP) | VAF 46/366 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.066); catalogued as rs876657749, COSV99860083; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CACNA1G | c.4810G>A p.V1604I | Missense Mutation (SNP) | VAF 13/94 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1177958111, COSV61731678; called by muse, mutect2, varscan2
- CADPS | c.2060G>A p.R687H | Missense Mutation (SNP) | VAF 12/99 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs573592664, COSV51868558; called by muse, mutect2, varscan2
- CALHM5 | c.786G>T p.W262C | Missense Mutation (SNP) | VAF 40/296 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100635574; called by muse, mutect2, varscan2
- CAMLG | c.763G>A p.E255K | Missense Mutation (SNP) | VAF 16/101 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs765331970, COSV51804427; called by muse, varscan2
- CAMTA1 | c.2210C>T p.P737L | Missense Mutation (SNP) | VAF 27/234 reads (12%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.062); catalogued as rs755139563, COSV100349041; called by muse, mutect2, varscan2
- CAND2 | c.1715C>T p.A572V (on ENST00000456430 / NM_001162499.2; = p.A479V on NM_012298.3) | Missense Mutation (SNP) | VAF 31/395 reads (8%) | SIFT tolerated (0.27); PolyPhen benign (0.007); catalogued as rs201492931; called by muse, mutect2
- CAPN2 | c.1433C>T p.P478L | Missense Mutation (SNP) | VAF 42/398 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1383039960, COSV54334980; called by muse, mutect2, varscan2
- CARD11 | c.1484C>T p.P495L | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.077); catalogued as rs760308478, COSV100829136, COSV62753963; called by muse, mutect2, varscan2
- CARD9 | c.1145G>A p.R382H | Missense Mutation (SNP) | VAF 38/289 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs540891739, COSV59998692; called by muse, mutect2, varscan2
- CARMIL3 | c.1925G>A p.R642H | Missense Mutation (SNP) | VAF 50/419 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.049); catalogued as rs755948859; called by muse, mutect2, varscan2
- CARMIL3 | c.2822del p.P941Lfs*31 | Frame Shift Del (DEL) | VAF 18/179 reads (10%) | catalogued as rs773353274, COSV57724683; called by mutect2, varscan2
- CARMIL3 | c.3386G>A p.R1129H | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs375532700; called by muse, mutect2, varscan2
- CBX4 | c.690dup p.N231Qfs*81 | Frame Shift Ins (INS) | VAF 12/102 reads (12%) | catalogued as rs772839792; called by mutect2, varscan2
- CC2D1B | c.1627C>T p.R543W | Missense Mutation (SNP) | VAF 20/150 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1014701743; called by muse, mutect2, varscan2
- CCAR2 | c.17G>A p.R6H | Missense Mutation (SNP) | VAF 19/202 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.976); catalogued as rs371733204; called by muse, mutect2, varscan2
- CCDC14 | c.2409del p.K803Nfs*8 (on ENST00000488653; = p.K755Nfs*8 on NM_022757.5) | Frame Shift Del (DEL) | VAF 29/243 reads (12%) | catalogued as rs751659778; called by mutect2, pindel, varscan2
- CCDC17 | c.484C>T p.R162C | Missense Mutation (SNP) | VAF 24/173 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); catalogued as COSV51972671; called by muse, mutect2, varscan2
- CCDC70 | c.637C>T p.R213C | Missense Mutation (SNP) | VAF 15/113 reads (13%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.431); catalogued as rs139558267; called by muse, mutect2, varscan2
- CCDC9B | c.609dup p.T204Hfs*56 | Frame Shift Ins (INS) | VAF 26/208 reads (13%) | catalogued as rs772754432; called by mutect2, varscan2
- CCL26 | c.178C>T p.R60W | Missense Mutation (SNP) | VAF 20/138 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.849); catalogued as rs150951637; called by muse, mutect2, varscan2
- CCL3L3 | c.211C>T p.R71W | Missense Mutation (SNP) | VAF 35/366 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.946); catalogued as rs1249997768; called by muse, mutect2
- CD2 | c.788G>A p.R263Q | Missense Mutation (SNP) | VAF 18/121 reads (15%) | SIFT tolerated (0.29); PolyPhen benign (0.228); catalogued as rs759707410, COSV65644143; called by muse, mutect2, varscan2
- CD2AP | c.1812C>T p.H604= | Splice Region (SNP) | VAF 15/129 reads (12%) | catalogued as rs140391156; called by muse, mutect2, varscan2
- CD81 | c.561+6C>T | Splice Region (SNP) | VAF 105/710 reads (15%) | catalogued as rs377337982; called by muse, mutect2, varscan2
- CD96 | c.1499C>T p.T500M (on ENST00000283285 / NM_198196.3; = p.T484M on NM_005816.5) | Missense Mutation (SNP) | VAF 27/272 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as rs140955483; ClinVar: likely benign; called by muse, mutect2, varscan2
- CDC14A | c.1439G>A p.R480Q | Missense Mutation (SNP) | VAF 19/169 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.865); catalogued as rs749988305, COSV100324271; called by muse, mutect2, varscan2
- CDC73 | c.467G>A p.R156H | Missense Mutation (SNP) | VAF 15/115 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as COSV66464849; called by muse, mutect2, varscan2
- CDCA2 | c.1783G>A p.E595K | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs144313074, COSV57949661; called by muse, mutect2, varscan2
- CDH16 | c.2281G>A p.V761M | Missense Mutation (SNP) | VAF 36/203 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs763289445, COSV55336208; called by muse, varscan2
- CDH2 | c.2092G>A p.V698M | Missense Mutation (SNP) | VAF 33/281 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs767117514; called by muse, mutect2, varscan2
- CDH23 | c.4096G>A p.A1366T | Missense Mutation (SNP) | VAF 25/201 reads (12%) | SIFT tolerated (0.48); PolyPhen benign (0.001); catalogued as rs1166886985; called by muse, mutect2, varscan2
- CDKN2B | c.382G>A p.V128I | Missense Mutation (SNP) | VAF 59/556 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.006); catalogued as rs747908376; called by muse, mutect2, varscan2
- CEACAM19 | c.298G>A p.V100M | Missense Mutation (SNP) | VAF 13/105 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs114307023; called by muse, mutect2, varscan2
- CELSR1 | c.6923C>T p.P2308L | Missense Mutation (SNP) | VAF 18/157 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.006); catalogued as rs765331834, COSV99419400; called by muse, mutect2, varscan2
- CENPE | c.7874A>G p.Q2625R | Missense Mutation (SNP) | VAF 14/168 reads (8%) | SIFT tolerated (0.84); PolyPhen benign (0.056); catalogued as rs772361306, COSV99478382; called by muse, mutect2
- CEP164 | c.1457G>A p.R486H | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs545471229; called by mutect2, varscan2
- CEP290 | c.614G>A p.R205Q | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT tolerated (0.56); PolyPhen benign (0.013); catalogued as rs547665147; called by mutect2, varscan2
- CEP72 | c.1274C>T p.T425M | Missense Mutation (SNP) | VAF 13/131 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.374); catalogued as rs200645880; called by muse, mutect2, varscan2
- CER1 | c.596C>T p.A199V | Missense Mutation (SNP) | VAF 29/283 reads (10%) | SIFT tolerated (0.27); PolyPhen benign (0.013); catalogued as rs140434620; called by muse, mutect2, varscan2
- CFAP206 | c.1430del p.N477Ifs*4 | Frame Shift Del (DEL) | VAF 22/100 reads (22%) | catalogued as rs751492244; called by mutect2, varscan2
- CFAP43 | c.4133G>A p.R1378Q | Missense Mutation (SNP) | VAF 16/147 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1240998046, COSV100829083; called by muse, mutect2, varscan2
- CFAP57 | c.2827C>T p.R943* | Nonsense Mutation (SNP) | VAF 15/81 reads (19%) | catalogued as rs745712926; called by muse, mutect2, varscan2
- CFAP74 | c.3460C>T p.R1154C | Missense Mutation (SNP) | VAF 21/166 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as rs556932137; called by muse, mutect2, varscan2
- CFP | c.146del p.G49Vfs*43 | Frame Shift Del (DEL) | VAF 20/120 reads (17%) | catalogued as rs749541242; called by mutect2, pindel, varscan2
- CGN | c.167G>A p.R56H | Missense Mutation (SNP) | VAF 43/268 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs373220207; called by muse, mutect2, varscan2
- CHAF1A | c.1867G>A p.D623N | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as rs1346214232; called by muse, mutect2, varscan2
- CHAT | c.145G>A p.G49R | Missense Mutation (SNP) | VAF 22/216 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs915451905; called by muse, mutect2, varscan2
- CHMP7 | c.493C>T p.R165C | Missense Mutation (SNP) | VAF 68/370 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.706); catalogued as rs757496234, COSV100500649; called by muse, mutect2, varscan2
- CHRM2 | c.169G>A p.V57I | Missense Mutation (SNP) | VAF 45/421 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.683); catalogued as rs143842239, COSV57767125; ClinVar: uncertain significance; called by muse, mutect2
- CHRM2 | c.736A>G p.N246D | Missense Mutation (SNP) | VAF 36/394 reads (9%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.744); catalogued as rs768949834; called by muse, mutect2
- CHRM4 | c.427C>T p.R143W | Missense Mutation (SNP) | VAF 48/385 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.531); catalogued as rs200330011, COSV63126655; called by muse, mutect2, varscan2
- CHRNA10 | c.701G>A p.R234H | Missense Mutation (SNP) | VAF 20/109 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs777354719; called by muse, mutect2, varscan2
- CHSY3 | c.2399T>C p.I800T | Missense Mutation (SNP) | VAF 36/269 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1561576086; called by muse, mutect2, varscan2
- CIITA | c.1962dup p.G655Rfs*94 | Frame Shift Ins (INS) | VAF 68/516 reads (13%) | catalogued as rs778982759; called by mutect2, varscan2
- CILP2 | c.1876C>T p.R626C | Missense Mutation (SNP) | VAF 31/294 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.582); catalogued as rs147580706; called by muse, mutect2, varscan2
- CISH | c.416G>A p.R139H (on ENST00000348721 / NM_145071.4; = p.R156H on NM_013324.6) | Missense Mutation (SNP) | VAF 84/666 reads (13%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.99); catalogued as rs1436502044; called by muse, mutect2, varscan2
- CLASRP | c.99+1G>A p.X33_splice | Splice Site (SNP) | VAF 15/79 reads (19%) | catalogued as COSV55512388; called by muse, mutect2, varscan2
- CLEC16A | c.2993C>T p.T998M | Missense Mutation (SNP) | VAF 30/263 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.168); catalogued as rs943483874, COSV55491155; called by muse, mutect2, varscan2
- CLEC1B | c.470G>A p.R157H | Missense Mutation (SNP) | VAF 32/276 reads (12%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as rs371171367; called by muse, mutect2, varscan2
- CLIP1 | c.1127C>T p.A376V | Missense Mutation (SNP) | VAF 16/139 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.728); catalogued as rs750993336; called by muse, mutect2, varscan2
- CMYA5 | c.3221C>T p.P1074L | Missense Mutation (SNP) | VAF 17/125 reads (14%) | SIFT tolerated (0.26); PolyPhen benign (0.034); catalogued as rs777880979, COSV71409725; called by muse, mutect2, varscan2
- CNGA4 | c.619G>A p.A207T | Missense Mutation (SNP) | VAF 41/341 reads (12%) | SIFT tolerated (0.51); PolyPhen benign (0.007); catalogued as rs773283676, COSV66006075; called by muse, mutect2, varscan2
- CNTN1 | c.2039G>A p.R680H | Missense Mutation (SNP) | VAF 28/232 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs770506056, COSV61645121; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CNTRL | c.4741G>A p.E1581K | Missense Mutation (SNP) | VAF 13/106 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.833); catalogued as rs751956745; called by muse, mutect2, varscan2
- COG8 | c.1535G>A p.R512H | Missense Mutation (SNP) | VAF 29/268 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV55341409; called by muse, mutect2, varscan2
- COL10A1 | c.70C>T p.R24* | Nonsense Mutation (SNP) | VAF 18/211 reads (9%) | catalogued as rs199808053; ClinVar: uncertain significance; called by muse, mutect2
- COL11A1 | c.3285del p.G1096Vfs*102 | Frame Shift Del (DEL) | VAF 14/156 reads (9%) | catalogued as COSV62181107; called by mutect2, pindel
- COL11A2 | c.3032del p.P1011Lfs*334 (on ENST00000341947 / NM_080680.3; = p.P904Lfs*334 on NM_080679.2) | Frame Shift Del (DEL) | VAF 40/338 reads (12%) | catalogued as rs1363500354; called by mutect2, pindel, varscan2
- COL18A1 | c.4694G>A p.R1565Q (on ENST00000359759 / NM_130444.3; = p.R1330Q on NM_030582.4) | Missense Mutation (SNP) | VAF 46/300 reads (15%) | SIFT tolerated (0.22); PolyPhen benign (0.078); catalogued as rs767494712; called by muse, mutect2, varscan2
- COL21A1 | c.1029G>A p.T343= | Splice Region (SNP) | VAF 6/42 reads (14%) | catalogued as rs373532211; called by mutect2, varscan2
- COL4A6 | c.4825G>A p.A1609T | Missense Mutation (SNP) | VAF 26/130 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.489); catalogued as rs756009266; called by muse, mutect2, varscan2
- COL4A6 | c.1553G>A p.R518Q | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated (0.4); PolyPhen benign (0.113); catalogued as rs772996187; called by muse, mutect2, varscan2
- COL5A1 | c.2278G>A p.G760R | Missense Mutation (SNP) | VAF 42/317 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1376035050, COSV65666647; called by muse, mutect2, varscan2
- COL5A2 | c.3604C>T p.R1202* | Nonsense Mutation (SNP) | VAF 18/195 reads (9%) | catalogued as COSV100880869; called by muse, mutect2
- COL7A1 | c.8683C>T p.R2895W | Missense Mutation (SNP) | VAF 29/405 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.05); catalogued as rs751882294, COSV56476352; called by muse, mutect2
- COL9A1 | c.929C>T p.P310L | Missense Mutation (SNP) | VAF 40/370 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.271); catalogued as rs1159414513, COSV57891772; called by muse, mutect2, varscan2
- COL9A3 | c.1401G>A p.E467= | Splice Region (SNP) | VAF 46/355 reads (13%) | catalogued as rs1048063823; called by muse, mutect2, varscan2
- COPG1 | c.586G>A p.A196T | Missense Mutation (SNP) | VAF 18/151 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1448297813, COSV59115075; called by muse, mutect2, varscan2
- CORO1A | c.481G>A p.V161M | Missense Mutation (SNP) | VAF 55/509 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as rs1311216868, COSV54632068; called by muse, mutect2, varscan2
- CPAMD8 | c.4189C>A p.L1397M (on ENST00000651564; = p.L1350M on NM_015692.5) | Missense Mutation (SNP) | VAF 29/204 reads (14%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.789); catalogued as COSV71596481; called by muse, mutect2, varscan2
- CREBBP | c.5830G>C p.A1944P | Missense Mutation (SNP) | VAF 15/136 reads (11%) | SIFT tolerated (0.72); PolyPhen benign (0.005); catalogued as COSV52131776; called by muse, mutect2, varscan2
- CRIPT | c.132del p.A45Qfs*86 | Frame Shift Del (DEL) | VAF 10/54 reads (19%) | catalogued as rs771238795; called by mutect2, varscan2
- CROCC | c.3370C>T p.R1124W | Missense Mutation (SNP) | VAF 22/157 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.172); catalogued as rs371156238; called by muse, mutect2, varscan2
- CRP | c.361G>A p.A121T | Missense Mutation (SNP) | VAF 43/346 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.041); catalogued as rs763547558, COSV54814322; called by muse, mutect2, varscan2
- CRTC1 | c.1277del p.P426Qfs*85 | Frame Shift Del (DEL) | VAF 14/113 reads (12%) | catalogued as rs760791352; called by mutect2, pindel, varscan2
- CSMD2 | c.8572C>T p.R2858C | Missense Mutation (SNP) | VAF 16/139 reads (12%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.832); catalogued as rs931136413, COSV99589134; called by muse, mutect2, varscan2
- CSPG5 | c.662G>A p.R221H | Missense Mutation (SNP) | VAF 34/308 reads (11%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.015); catalogued as COSV99274306; called by muse, mutect2, varscan2
- CT83 | c.65G>A p.R22H | Missense Mutation (SNP) | VAF 28/106 reads (26%) | SIFT tolerated (0.38); PolyPhen benign (0.013); catalogued as COSV64141123; called by muse, mutect2, varscan2
- CTSH | c.415G>A p.G139S | Missense Mutation (SNP) | VAF 15/145 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766261285, COSV54985440, COSV99585664; called by muse, mutect2, varscan2
- CTTN | c.1325C>T p.P442L | Missense Mutation (SNP) | VAF 13/115 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs374031706; called by muse, mutect2, varscan2
- CUX1 | c.1289del p.P430Lfs*27 | Frame Shift Del (DEL) | VAF 7/62 reads (11%) | catalogued as rs782381199; called by pindel, varscan2
- CXCR2 | c.707G>A p.R236H | Missense Mutation (SNP) | VAF 54/546 reads (10%) | SIFT tolerated (0.66); PolyPhen benign (0.021); catalogued as rs144013681; ClinVar: uncertain significance; called by muse, mutect2
- CYCS | c.115C>T p.R39W | Missense Mutation (SNP) | VAF 30/270 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.161); catalogued as rs11548791; called by muse, mutect2, varscan2
- CYFIP1 | c.2950G>A p.V984M | Missense Mutation (SNP) | VAF 14/227 reads (6%) | SIFT tolerated (0.35); PolyPhen benign (0.045); catalogued as rs1231311934, COSV100488837; called by muse, mutect2
- CYFIP1 | c.1645C>T p.R549C | Missense Mutation (SNP) | VAF 14/111 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as rs1227046266; called by muse, mutect2, varscan2
- CYP4F22 | c.737G>A p.R246H | Missense Mutation (SNP) | VAF 30/387 reads (8%) | SIFT tolerated (0.42); PolyPhen benign (0.005); catalogued as rs184021211, COSV54106897; called by muse, mutect2
- DAB1 | c.1130C>T p.P377L (on ENST00000371231; = p.P344L on NM_021080.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/198 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.506); catalogued as rs752475579; called by muse, mutect2, varscan2
- DAGLB | c.1163C>T p.A388V | Missense Mutation (SNP) | VAF 37/309 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.87); catalogued as rs745496150, COSV51703494; called by muse, mutect2, varscan2
- DCLRE1A | c.1033A>T p.K345* | Nonsense Mutation (SNP) | VAF 17/160 reads (11%) | catalogued as COSV63748120; called by muse, mutect2, varscan2
- DDR2 | c.1414G>A p.D472N | Missense Mutation (SNP) | VAF 39/379 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.349); catalogued as rs1219740609, COSV63371661; called by muse, mutect2
- DELE1 | c.41G>A p.R14H | Missense Mutation (SNP) | VAF 16/92 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs1488432158, COSV99519994; called by muse, mutect2, varscan2
- DGAT1 | c.981G>A p.A327= | Splice Region (SNP) | VAF 71/384 reads (18%) | catalogued as rs143753756; called by muse, mutect2, varscan2
- DGCR2 | c.112C>T p.R38C | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.79); catalogued as rs751483287, COSV54216745; called by mutect2, varscan2
- DGKD | c.2108C>T p.P703L (on ENST00000264057 / NM_152879.3; = p.P659L on NM_003648.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/123 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.009); catalogued as rs896873247, COSV99894992; called by muse, mutect2, varscan2
- DGKD | c.3298G>A p.D1100N (on ENST00000264057 / NM_152879.3; = p.D1056N on NM_003648.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/197 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.042); catalogued as rs779504822; called by muse, mutect2, varscan2
- DHODH | c.316G>A p.G106R | Missense Mutation (SNP) | VAF 45/386 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs561068542, COSV54664120; called by muse, mutect2, varscan2
- DIDO1 | c.1425del p.E476Rfs*4 | Frame Shift Del (DEL) | VAF 19/162 reads (12%) | catalogued as rs762377755; called by mutect2, varscan2
- DLGAP1 | c.2411G>A p.R804Q | Missense Mutation (SNP) | VAF 39/302 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.166); catalogued as COSV100232299; called by muse, mutect2, varscan2
- DLGAP3 | c.1283G>A p.R428H | Missense Mutation (SNP) | VAF 45/424 reads (11%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.764); catalogued as rs1159145122; called by muse, varscan2
- DLGAP4 | c.347G>A p.R116H | Missense Mutation (SNP) | VAF 24/222 reads (11%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.987); catalogued as rs776984875, COSV59414622; called by muse, mutect2, varscan2
- DMBT1 | c.2251C>T p.R751* | Nonsense Mutation (SNP) | VAF 44/424 reads (10%) | catalogued as rs775863322, COSV57565379; called by muse, mutect2, varscan2
- DMXL2 | c.1435C>T p.R479* | Nonsense Mutation (SNP) | VAF 18/161 reads (11%) | catalogued as rs1216748626; called by muse, mutect2, varscan2
- DNA2 | c.2335del p.S779Hfs*6 | Frame Shift Del (DEL) | VAF 8/42 reads (19%) | catalogued as rs745893364; called by mutect2, varscan2
- DNAJC10 | c.1911del p.P639Qfs*22 | Frame Shift Del (DEL) | VAF 10/81 reads (12%) | catalogued as rs1283431287; called by mutect2, pindel, varscan2
- DNAJC2 | c.1173-7del | Splice Region (DEL) | VAF 18/110 reads (16%) | catalogued as rs538091160; called by mutect2, varscan2
- DNHD1 | c.7673C>T p.A2558V | Missense Mutation (SNP) | VAF 59/590 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99600074; called by muse, mutect2, varscan2
- DNM1L | c.415G>A p.V139I | Missense Mutation (SNP) | VAF 17/156 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs150170255; ClinVar: likely benign; called by muse, mutect2, varscan2
- DNMT1 | c.2395G>A p.A799T | Missense Mutation (SNP) | VAF 20/217 reads (9%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.837); catalogued as rs373366822; called by muse, mutect2
- DNMT1 | c.1772C>T p.T591M | Missense Mutation (SNP) | VAF 51/327 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV61585005; called by muse, mutect2, varscan2
- DNMT3B | c.1012G>A p.G338R | Missense Mutation (SNP) | VAF 53/381 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.409); catalogued as rs1013448701, COSV99140556; called by muse, mutect2, varscan2
- DOC2A | c.191del p.P64Lfs*27 | Frame Shift Del (DEL) | VAF 42/318 reads (13%) | catalogued as rs753153258; called by mutect2, pindel, varscan2
- DOCK7 | c.3175C>T p.R1059* (on ENST00000635253 / NM_001367561.1; = p.R1028* on NM_033407.3) | Nonsense Mutation (SNP) | VAF 9/81 reads (11%) | catalogued as rs1252995089; called by muse, mutect2, varscan2
- DPY19L1 | c.353G>A p.R118Q | Missense Mutation (SNP) | VAF 17/130 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs747280371, COSV60584161; called by muse, mutect2, varscan2
- DSG1 | c.1487C>T p.P496L | Missense Mutation (SNP) | VAF 38/168 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.014); catalogued as rs143742729; called by muse, mutect2, varscan2
- DSPP | c.2540G>A p.S847N | Missense Mutation (SNP) | VAF 61/490 reads (12%) | SIFT tolerated, low confidence (0.81); PolyPhen possibly damaging (0.859); catalogued as rs1220416323; called by muse, mutect2, varscan2
- DUS2 | c.643G>A p.G215R | Missense Mutation (SNP) | VAF 13/116 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1277433054, COSV99076145; called by muse, mutect2, varscan2
- DYNC1H1 | c.6871G>A p.V2291M | Missense Mutation (SNP) | VAF 50/407 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs779194599; called by muse, mutect2, varscan2
- E2F5 | c.962C>T p.P321L | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); catalogued as rs369086172; called by muse, mutect2, varscan2
- EBF2 | c.1292G>A p.G431D | Missense Mutation (SNP) | VAF 17/111 reads (15%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.211); catalogued as COSV68778137; called by muse, mutect2, varscan2
- ECE1 | c.1075G>A p.V359M | Missense Mutation (SNP) | VAF 21/201 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as rs199950512; called by muse, mutect2, varscan2
- ECHDC3 | c.722C>T p.A241V | Missense Mutation (SNP) | VAF 28/211 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.088); catalogued as rs1462920977; called by muse, mutect2, varscan2
- EFR3A | c.614T>C p.M205T | Missense Mutation (SNP) | VAF 21/97 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.529); catalogued as rs768626078; called by muse, mutect2, varscan2
- EGFLAM | c.2490G>A p.T830= (on ENST00000354891 / NM_001205301.2; = p.A822= on NM_152403.4) | Splice Region (SNP) | VAF 11/88 reads (13%) | catalogued as rs760338980, COSV59300352; called by muse, mutect2, varscan2
- EGR3 | c.1144G>A p.V382M | Missense Mutation (SNP) | VAF 45/205 reads (22%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.477); catalogued as rs1292913772, COSV100416215; called by muse, mutect2, varscan2
- EHMT1 | c.1568G>A p.R523Q | Missense Mutation (SNP) | VAF 32/436 reads (7%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.556); catalogued as rs1369490460, COSV58377110; called by muse, mutect2
- EHMT1 | c.3689G>A p.R1230H | Missense Mutation (SNP) | VAF 28/282 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1454873074; called by muse, mutect2
- EIF2AK3 | c.502C>T p.R168C | Missense Mutation (SNP) | VAF 32/273 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs762206822, COSV57547131; called by muse, mutect2, varscan2
- EIF3A | c.3391C>T p.R1131C | Missense Mutation (SNP) | VAF 42/341 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as rs765075620; called by muse, varscan2
- EIF3A | c.1813C>T p.R605W | Missense Mutation (SNP) | VAF 23/158 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV64963369; called by muse, mutect2, varscan2
- EIF3B | c.1990C>T p.R664C | Missense Mutation (SNP) | VAF 22/155 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1367743504, COSV62802746; called by muse, mutect2, varscan2
- EIF4A1 | c.955C>T p.R319C | Missense Mutation (SNP) | VAF 31/263 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.728); catalogued as COSV51512462, COSV99548666; called by muse, mutect2, varscan2
- EIF4G1 | c.1305del p.T436Pfs*86 (on ENST00000346169 / NM_198241.3; = p.T240Pfs*86 on NM_004953.5) | Frame Shift Del (DEL) | VAF 28/242 reads (12%) | catalogued as COSV104407217; called by pindel, varscan2
- ELMO3 | c.250G>A p.A84T (on ENST00000652269; = p.A31T on NM_024712.5) | Missense Mutation (SNP) | VAF 41/448 reads (9%) | SIFT tolerated (0.39); PolyPhen benign (0.007); catalogued as rs909315713; called by muse, mutect2
- ENO4 | c.724G>A p.V242M (on ENST00000622726; = p.V241M on NM_001242699.2) | Missense Mutation (SNP) | VAF 16/122 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs954190090; called by muse, mutect2, varscan2
- ENPEP | c.1083C>A p.N361K | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs760534405, COSV54452086; called by muse, mutect2, varscan2
- ENPP2 | c.1238C>T p.T413M (on ENST00000075322 / NM_001040092.3; = p.T465M on NM_006209.5) | Missense Mutation (SNP) | VAF 15/99 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs202191091; called by muse, mutect2, varscan2
- EP300 | c.2512C>T p.R838C | Missense Mutation (SNP) | VAF 21/204 reads (10%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.869); catalogued as rs1215000818, COSV54335708, COSV54338235; called by muse, mutect2, varscan2
- EPB41L1 | c.16G>A p.G6S | Missense Mutation (SNP) | VAF 27/207 reads (13%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.997); catalogued as rs1258886245; called by muse, mutect2, varscan2
- EPHA2 | c.1474G>A p.V492M | Missense Mutation (SNP) | VAF 46/348 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.091); catalogued as rs141123184; called by muse, mutect2, varscan2
- EPHA2 | c.682G>A p.G228S | Missense Mutation (SNP) | VAF 66/484 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1223374611, COSV64452319; called by muse, varscan2
- EPHA4 | c.2584C>T p.Q862* | Nonsense Mutation (SNP) | VAF 14/138 reads (10%) | catalogued as COSV56036930; called by muse, mutect2
- EPHB1 | c.2072G>A p.R691Q | Missense Mutation (SNP) | VAF 29/176 reads (16%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.996); catalogued as rs1384145752, COSV67657811, COSV67672093; called by muse, mutect2, varscan2
- EPHB2 | c.1120C>T p.R374C | Missense Mutation (SNP) | VAF 18/166 reads (11%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.988); catalogued as rs756230281; called by muse, mutect2, varscan2
- EPHX2 | c.364C>A p.L122I | Missense Mutation (SNP) | VAF 41/278 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.428); catalogued as rs1231951536; called by muse, mutect2, varscan2
- EPM2A | c.619C>T p.R207C | Missense Mutation (SNP) | VAF 51/453 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as rs186710183; called by muse, mutect2, varscan2
- EPS8L2 | c.536_538del p.K179del | In Frame Del (DEL) | VAF 25/189 reads (13%) | catalogued as rs749057351; called by pindel, varscan2
- ERBB2 | c.3641G>A p.S1214N | Missense Mutation (SNP) | VAF 26/241 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0.078); catalogued as COSV99509218; called by muse, mutect2, varscan2
- ERN2 | c.2320del p.Q774Rfs*35 | Frame Shift Del (DEL) | VAF 9/83 reads (11%) | catalogued as rs1567242682; called by mutect2, pindel, varscan2
- ESPNL | c.1565G>A p.R522H | Missense Mutation (SNP) | VAF 46/343 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.939); catalogued as rs572001508, COSV58032451; called by muse, mutect2, varscan2
- EVPL | c.4237C>T p.R1413W | Missense Mutation (SNP) | VAF 54/367 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); catalogued as rs1038019114, COSV56916360; called by muse, mutect2, varscan2
- EVX1 | c.704G>A p.R235H | Missense Mutation (SNP) | VAF 18/144 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56086213; called by muse, mutect2, varscan2
- EXD3 | c.20C>T p.A7V | Missense Mutation (SNP) | VAF 21/216 reads (10%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.003); catalogued as rs949854994; called by muse, mutect2
- F11R | c.682C>T p.R228C | Missense Mutation (SNP) | VAF 20/131 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs199703485, COSV99231369; called by muse, mutect2, varscan2
- FAM122B | c.710C>T p.S237L (on ENST00000370790 / NM_001166599.3; = p.S238L on NM_145284.5) | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.186); catalogued as rs770180656; called by muse, mutect2, varscan2
- FAM161B | c.255dup p.E86Rfs*26 (on ENST00000651776; = p.E23Rfs*26 on NM_152445.3) | Frame Shift Ins (INS) | VAF 13/137 reads (9%) | catalogued as rs775951198; called by mutect2, pindel, varscan2
- FAM205A | c.2576C>T p.A859V | Missense Mutation (SNP) | VAF 48/393 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs1320255603; called by muse, mutect2, varscan2
- FAM83D | c.622G>A p.D208N | Missense Mutation (SNP) | VAF 16/274 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1302077496, COSV54159342; called by muse, mutect2
- FAM83H | c.1043G>A p.R348H | Missense Mutation (SNP) | VAF 22/121 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs1350463425; called by muse, mutect2, varscan2
- FAM83H | c.393del p.D132Tfs*12 | Frame Shift Del (DEL) | VAF 26/164 reads (16%) | catalogued as rs782484545, COSV101186939, COSV101187094; called by mutect2, pindel, varscan2
- FAM91A1 | c.1135G>A p.A379T | Missense Mutation (SNP) | VAF 16/155 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as rs760648737, COSV58235570; called by muse, mutect2, varscan2
- FARP1 | c.1469del p.G490Efs*7 | Frame Shift Del (DEL) | VAF 8/72 reads (11%) | catalogued as rs781296424, COSV60339953; called by mutect2, pindel, varscan2
- FASTKD5 | c.767G>A p.R256H | Missense Mutation (SNP) | VAF 19/135 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.005); catalogued as rs774251244, COSV53910223; called by muse, mutect2, varscan2
- FBF1 | c.2656G>A p.E886K (on ENST00000586717; = p.E900K on NM_001319193.1) | Missense Mutation (SNP) | VAF 37/302 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs907231532, COSV100045667; called by muse, mutect2, varscan2
- FBN2 | c.2150G>A p.R717H | Missense Mutation (SNP) | VAF 19/224 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); catalogued as rs773896695, COSV52491204; called by muse, mutect2
- FBN3 | c.1052C>T p.P351L | Missense Mutation (SNP) | VAF 9/94 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.013); catalogued as rs1267100569; called by muse, mutect2, varscan2
- FBXL18 | c.1246C>T p.R416C | Missense Mutation (SNP) | VAF 15/103 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.025); catalogued as rs771902653; called by muse, mutect2, varscan2
- FBXO5 | c.679G>T p.G227* | Nonsense Mutation (SNP) | VAF 25/212 reads (12%) | catalogued as COSV99999893; called by muse, mutect2, varscan2
- FBXO6 | c.746G>A p.R249Q | Missense Mutation (SNP) | VAF 53/451 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as rs779140958; called by muse, mutect2, varscan2
- FCHO2 | c.44del p.N15Ifs*11 | Frame Shift Del (DEL) | VAF 5/29 reads (17%) | catalogued as rs768979093, COSV55110370; called by mutect2, pindel, varscan2
- FFAR4 | c.829C>T p.R277W | Missense Mutation (SNP) | VAF 31/206 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs762500408, COSV65159884; called by muse, mutect2, varscan2
- FKTN | c.509C>T p.A170V | Missense Mutation (SNP) | VAF 18/268 reads (7%) | SIFT tolerated (0.71); PolyPhen benign (0.001); catalogued as rs119464997, CM091569; called by muse, mutect2
- FLG | c.2060A>C p.N687T | Missense Mutation (SNP) | VAF 89/752 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs112669796, COSV64243050; called by mutect2, varscan2
- FLI1 | c.530G>A p.R177H | Missense Mutation (SNP) | VAF 46/456 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.051); catalogued as rs370316451; called by muse, mutect2, varscan2
- FLNC | c.6802G>A p.E2268K | Missense Mutation (SNP) | VAF 76/566 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.014); catalogued as rs1156444972, COSV57955133; called by muse, mutect2, varscan2
- FMNL1 | c.337C>T p.R113* | Nonsense Mutation (SNP) | VAF 21/173 reads (12%) | catalogued as rs1245574309, COSV58955234; called by muse, mutect2, varscan2
- FN1 | c.6304G>A p.G2102S (on ENST00000359671 / NM_001365524.2; = p.G2012S on NM_212476.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/324 reads (8%) | SIFT tolerated (0.76); PolyPhen benign (0.001); catalogued as rs775537486; called by muse, mutect2
- FPR3 | c.350C>T p.T117I | Missense Mutation (SNP) | VAF 16/202 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.506); catalogued as COSV100200654; called by muse, mutect2
- FRAS1 | c.7988C>T p.A2663V | Missense Mutation (SNP) | VAF 22/272 reads (8%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as rs779574423, COSV53615064; called by muse, mutect2
- FRMD8 | c.320G>A p.R107H | Missense Mutation (SNP) | VAF 19/156 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs779476479; called by muse, mutect2, varscan2
- FRMPD2 | c.790G>A p.A264T | Missense Mutation (SNP) | VAF 20/168 reads (12%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs145688226; called by muse, mutect2, varscan2
- FUCA2 | c.1361C>A p.P454Q | Missense Mutation (SNP) | VAF 26/167 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.283); catalogued as rs200632280, COSV99136285; called by muse, mutect2, varscan2
- FURIN | c.655G>A p.A219T | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs775431473, COSV51577539; called by mutect2, varscan2
- FXR2 | c.1768C>A p.R590S | Missense Mutation (SNP) | VAF 44/318 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.972); catalogued as COSV100001979; called by mutect2, varscan2
- FXR2 | c.1489del p.R497Gfs*15 | Frame Shift Del (DEL) | VAF 9/82 reads (11%) | catalogued as rs1567747777; called by mutect2, pindel, varscan2
- FZD2 | c.1210G>A p.V404I | Missense Mutation (SNP) | VAF 28/227 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.97); catalogued as COSV59528462; called by muse, mutect2, varscan2
- GABBR1 | c.1721dup p.A575Sfs*2 | Frame Shift Ins (INS) | VAF 20/126 reads (16%) | catalogued as rs777471402; called by mutect2, varscan2
- GABBR1 | c.706G>A p.D236N | Missense Mutation (SNP) | VAF 14/160 reads (9%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.805); catalogued as rs1253384281; called by muse, mutect2
- GABRR1 | c.481G>A p.V161M | Missense Mutation (SNP) | VAF 42/338 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs765790320, COSV65620572; called by muse, mutect2, varscan2
- GAK | c.1541C>T p.A514V | Missense Mutation (SNP) | VAF 17/155 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.031); catalogued as rs899151597; called by muse, mutect2, varscan2
- GALNT17 | c.1012G>A p.G338S | Missense Mutation (SNP) | VAF 23/141 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.904); catalogued as rs761569221, COSV61164829, COSV61170298; called by muse, mutect2, varscan2
- GALNT8 | c.823G>A p.A275T | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as rs746921515, COSV52897372; called by mutect2, varscan2
- GBF1 | c.5317G>A p.E1773K (on ENST00000369983 / NM_001377137.1; = p.E1772K on NM_004193.3) | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT tolerated, low confidence (0.7); PolyPhen benign (0.001); catalogued as rs528679712; called by mutect2, varscan2
- GCN1 | c.5837C>T p.A1946V | Missense Mutation (SNP) | VAF 21/140 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1462758856; called by muse, mutect2, varscan2
- GCN1 | c.1117G>A p.V373M | Missense Mutation (SNP) | VAF 29/191 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.371); catalogued as rs375647573; called by muse, mutect2, varscan2
- GDI2 | c.868C>T p.R290W | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs533312902, COSV100050145; called by muse, mutect2, varscan2
- GDNF | c.323G>A p.R108Q | Missense Mutation (SNP) | VAF 21/233 reads (9%) | SIFT tolerated (0.24); PolyPhen benign (0.009); catalogued as rs762832373, COSV58479237; called by muse, mutect2
- GDPD2 | c.1397C>T p.S466L | Missense Mutation (SNP) | VAF 17/88 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs747682076, COSV65531902; called by muse, mutect2, varscan2
- GFRA1 | c.782C>T p.A261V | Missense Mutation (SNP) | VAF 50/380 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.638); catalogued as rs754562462, COSV100816175, COSV62607971; called by muse, mutect2, varscan2
- GJD2 | c.230G>A p.R77H | Missense Mutation (SNP) | VAF 64/468 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV51748092; called by muse, mutect2, varscan2
- GJD4 | c.904G>A p.A302T | Missense Mutation (SNP) | VAF 17/154 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0.04); catalogued as rs1031354856; called by muse, mutect2, varscan2
- GLB1 | c.895C>T p.R299C | Missense Mutation (SNP) | VAF 34/346 reads (10%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.742); catalogued as rs1430384579, CD105074; called by muse, mutect2
- GLYR1 | c.934C>T p.R312C | Missense Mutation (SNP) | VAF 14/114 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.745); catalogued as rs756662561; called by muse, mutect2, varscan2
- GMEB2 | c.1186G>A p.V396M | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.061); catalogued as rs371767818; called by muse, mutect2, varscan2
- GMPPA | c.953G>A p.R318Q | Missense Mutation (SNP) | VAF 17/150 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs149492263; called by muse, mutect2, varscan2
- GNA14 | c.628C>T p.R210W | Missense Mutation (SNP) | VAF 11/95 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs377352484; called by muse, mutect2, varscan2
- GNAS | c.1154G>A p.R385H | Missense Mutation (SNP) | VAF 29/284 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.983); catalogued as CM940874, COSV55677425, COSV55683375; called by muse, mutect2
- GOLGA3 | c.4142C>T p.T1381M | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as rs749482676; called by mutect2, varscan2
- GOLGA4 | c.1333G>A p.E445K | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs564717378; called by mutect2, varscan2
- GOLGB1 | c.572A>C p.Q191P | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.201); catalogued as rs144140533; called by mutect2, varscan2
- GPI | c.229G>A p.V77M | Missense Mutation (SNP) | VAF 30/254 reads (12%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.962); catalogued as rs201126335; called by muse, mutect2, varscan2
- GPR149 | c.882del p.T295Lfs*10 | Frame Shift Del (DEL) | VAF 22/207 reads (11%) | catalogued as COSV101078087; called by mutect2, pindel, varscan2
- GPR18 | c.508G>A p.A170T | Missense Mutation (SNP) | VAF 34/229 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs138108915; called by muse, varscan2
- GPR6 | c.923C>T p.A308V | Missense Mutation (SNP) | VAF 34/294 reads (12%) | SIFT tolerated (0.59); PolyPhen benign (0.028); catalogued as rs575728346, COSV51572588, COSV51573074; called by muse, mutect2, varscan2
- GRIN1 | c.2662G>A p.A888T | Missense Mutation (SNP) | VAF 65/476 reads (14%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.971); catalogued as COSV59294870; called by mutect2, varscan2
- GRIP2 | c.2353C>T p.R785C (on ENST00000619221; = p.R688C on NM_001080423.4) | Missense Mutation (SNP) | VAF 7/97 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.944); catalogued as rs951074647; called by muse, mutect2
- GRM1 | c.814C>T p.R272* | Nonsense Mutation (SNP) | VAF 40/363 reads (11%) | catalogued as COSV51108019; called by muse, varscan2
- GRM4 | c.1963C>T p.R655C | Missense Mutation (SNP) | VAF 58/444 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs1419346763; called by muse, varscan2
- GRM6 | c.1169G>A p.G390D | Missense Mutation (SNP) | VAF 42/420 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.403); catalogued as rs763837722; called by muse, mutect2
- GRM8 | c.2267G>A p.S756N | Missense Mutation (SNP) | VAF 12/143 reads (8%) | SIFT tolerated (0.83); PolyPhen benign (0.012); catalogued as COSV58815027; called by muse, mutect2
- GSE1 | c.1541A>G p.Q514R | Missense Mutation (SNP) | VAF 18/143 reads (13%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.99); catalogued as rs1340992648, COSV53670955; called by muse, mutect2, varscan2
- GTF2IRD2 | c.2017G>A p.V673M | Missense Mutation (SNP) | VAF 41/357 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1554416399; called by muse, mutect2, varscan2
- GTF3C1 | c.1321C>T p.R441W | Missense Mutation (SNP) | VAF 19/184 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1180139242, COSV62240412; called by muse, mutect2, varscan2
- GTPBP4 | c.1743G>T p.R581S | Missense Mutation (SNP) | VAF 22/95 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.04); catalogued as rs1390916999; called by muse, mutect2, varscan2
- H3C2 | c.290G>A p.C97Y | Missense Mutation (SNP) | VAF 11/115 reads (10%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.217); catalogued as COSV52520191, COSV99451646; called by muse, mutect2
- HACD4 | c.689del p.K230Rfs*45 | Frame Shift Del (DEL) | VAF 30/122 reads (25%) | catalogued as rs768797944; called by mutect2, varscan2
- HAS1 | c.1279C>T p.R427C | Missense Mutation (SNP) | VAF 35/302 reads (12%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.676); catalogued as rs747388837; called by muse, mutect2, varscan2
- HAUS4 | c.898C>T p.R300C | Missense Mutation (SNP) | VAF 16/114 reads (14%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.997); catalogued as rs1473313395, COSV52826942; called by muse, mutect2, varscan2
- HDAC3 | c.670C>T p.R224W | Missense Mutation (SNP) | VAF 15/111 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs748394744; called by muse, mutect2, varscan2
- HDAC7 | c.2645G>A p.R882H (on ENST00000427332; = p.R921H on NM_015401.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/187 reads (12%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs771719953; called by muse, mutect2, varscan2
- HDLBP | c.3418G>A p.A1140T | Missense Mutation (SNP) | VAF 9/149 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.23); catalogued as COSV60500058; called by muse, mutect2
- HECTD1 | c.3473A>G p.Y1158C | Missense Mutation (SNP) | VAF 17/142 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101237539; called by muse, mutect2, varscan2
- HECTD4 | c.9719C>G p.A3240G | Missense Mutation (SNP) | VAF 21/192 reads (11%) | SIFT tolerated (0.25); PolyPhen benign (0.124); catalogued as COSV101108368, COSV66387887; called by mutect2, varscan2
- HECW2 | c.1738G>A p.A580T | Missense Mutation (SNP) | VAF 13/107 reads (12%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); catalogued as rs776211568, COSV99649515; called by muse, mutect2, varscan2
- HELZ | c.2024C>T p.T675M | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1567852446; called by muse, mutect2, varscan2
- HELZ2 | c.1241C>T p.A414V | Missense Mutation (SNP) | VAF 36/312 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.019); catalogued as rs757998203, COSV64410362; called by muse, mutect2, varscan2
- HERC1 | c.5947C>T p.R1983C | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs781450433, COSV101496677; called by mutect2, varscan2
- HIVEP1 | c.589G>A p.D197N | Missense Mutation (SNP) | VAF 19/183 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1279682789; called by muse, mutect2, varscan2
- HIVEP1 | c.5615G>A p.R1872Q | Missense Mutation (SNP) | VAF 18/173 reads (10%) | SIFT tolerated (0.49); PolyPhen benign (0.013); catalogued as rs1368992008, COSV101045889; called by muse, mutect2, varscan2
- HMOX1 | c.338G>A p.R113H | Missense Mutation (SNP) | VAF 66/432 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0.022); catalogued as rs11555830; called by muse, mutect2, varscan2
- HNF1A | c.1322C>T p.T441M | Missense Mutation (SNP) | VAF 15/160 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as rs371544082; called by muse, mutect2
- HNRNPCL1 | c.439C>T p.R147C | Missense Mutation (SNP) | VAF 34/423 reads (8%) | SIFT tolerated (0.05); PolyPhen benign (0.052); catalogued as rs763323069; called by muse, mutect2
- HNRNPH2 | c.698G>A p.R233H | Missense Mutation (SNP) | VAF 34/137 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.012); catalogued as rs782017930; called by muse, mutect2, varscan2
- HOXB7 | c.191del p.G64Afs*99 | Frame Shift Del (DEL) | VAF 12/68 reads (18%) | catalogued as rs761197780; called by mutect2, varscan2
- HR | c.1178G>A p.C393Y | Missense Mutation (SNP) | VAF 47/328 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1164876541; called by muse, mutect2, varscan2
- HROB | c.883C>T p.R295C | Missense Mutation (SNP) | VAF 44/409 reads (11%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.731); catalogued as rs749407735, COSV99809277; called by muse, mutect2, varscan2
- HS6ST1 | c.1126G>A p.E376K | Missense Mutation (SNP) | VAF 42/377 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.053); catalogued as rs766302801, COSV52126896; called by muse, mutect2, varscan2
- HSPG2 | c.4314G>A p.T1438= | Splice Region (SNP) | VAF 32/284 reads (11%) | catalogued as rs371330305; called by muse, mutect2, varscan2
- HTR1B | c.590C>T p.S197L | Missense Mutation (SNP) | VAF 35/314 reads (11%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs1366698596; called by muse, mutect2, varscan2
- IAH1 | c.494C>T p.A165V | Missense Mutation (SNP) | VAF 24/113 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.902); catalogued as rs375131640; called by muse, mutect2, varscan2
- IFIT1 | c.785G>A p.R262Q | Missense Mutation (SNP) | VAF 15/135 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.089); catalogued as rs749838277, COSV65661045; called by muse, mutect2, varscan2
- IFIT2 | c.1127G>A p.R376Q | Missense Mutation (SNP) | VAF 51/331 reads (15%) | SIFT tolerated (0.44); PolyPhen benign (0.005); catalogued as rs199839737; called by muse, mutect2, varscan2
- IFNA8 | c.373C>T p.Q125* | Nonsense Mutation (SNP) | VAF 53/365 reads (15%) | catalogued as COSV66504521; called by muse, mutect2, varscan2
- IFNAR1 | c.1222G>A p.A408T | Missense Mutation (SNP) | VAF 12/93 reads (13%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.965); catalogued as rs754602682; called by muse, mutect2, varscan2
- IFNLR1 | c.901G>A p.G301R | Missense Mutation (SNP) | VAF 12/115 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV59527329; called by muse, mutect2, varscan2
- IFT140 | c.3901G>A p.D1301N | Missense Mutation (SNP) | VAF 13/135 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.079); catalogued as rs754625031, COSV63697781; called by muse, mutect2, varscan2
- IFT140 | c.2425C>T p.R809C | Missense Mutation (SNP) | VAF 17/157 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs755748472, COSV99559675; called by muse, mutect2, varscan2
- IFT172 | c.4136G>A p.R1379H | Missense Mutation (SNP) | VAF 16/150 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.055); catalogued as rs772212247, COSV53134855; called by muse, mutect2
- IFT43 | c.445-1G>A p.X149_splice (on ENST00000314067 / NM_001102564.3; = p.X154_splice on NM_052873.3) | Splice Site (SNP) | VAF 20/524 reads (4%) | catalogued as COSV53139471; called by muse, mutect2
- IGF2R | c.6376G>A p.A2126T | Missense Mutation (SNP) | VAF 10/89 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs888327107, COSV100807452; called by muse, mutect2, varscan2
- IGSF10 | c.2401G>A p.A801T | Missense Mutation (SNP) | VAF 29/332 reads (9%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs760939504, COSV56788898; called by muse, mutect2
- IGSF9 | c.2287C>T p.R763C (on ENST00000368094 / NM_001135050.2; = p.R747C on NM_020789.4) | Missense Mutation (SNP) | VAF 23/268 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.432); catalogued as COSV63638680; called by muse, mutect2
- IL12RB2 | c.1558G>T p.A520S | Missense Mutation (SNP) | VAF 59/477 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.673); catalogued as rs200957598; called by muse, mutect2, varscan2
- IL17RD | c.1058G>A p.R353Q | Missense Mutation (SNP) | VAF 17/135 reads (13%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as rs199540136, COSV56343740; called by muse, mutect2, varscan2
- IL25 | c.457A>G p.K153E | Missense Mutation (SNP) | VAF 38/271 reads (14%) | SIFT tolerated (0.91); PolyPhen benign (0.096); catalogued as rs768668851; called by muse, mutect2, varscan2
- ILVBL | c.965G>A p.R322Q | Missense Mutation (SNP) | VAF 18/99 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs980467726, CM142439; called by muse, mutect2, varscan2
- INPPL1 | c.3424C>T p.R1142C | Missense Mutation (SNP) | VAF 33/230 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.348); catalogued as rs374001069; called by muse, mutect2, varscan2
- INTS3 | c.2963G>A p.R988Q | Missense Mutation (SNP) | VAF 22/219 reads (10%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.947); catalogued as rs770973052; called by muse, mutect2, varscan2
- IP6K2 | c.1070A>G p.E357G | Missense Mutation (SNP) | VAF 60/477 reads (13%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.637); catalogued as rs1259712228; called by muse, mutect2, varscan2
- IP6K3 | c.308C>T p.A103V | Missense Mutation (SNP) | VAF 40/355 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0.432); catalogued as rs778295599, COSV99539499; called by muse, mutect2, varscan2
- IPO13 | c.2636G>A p.R879H | Missense Mutation (SNP) | VAF 24/240 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.545); catalogued as rs147658570, COSV99664366; called by muse, mutect2, varscan2
- IQCE | c.250G>A p.A84T | Missense Mutation (SNP) | VAF 21/121 reads (17%) | SIFT tolerated (0.61); PolyPhen benign (0.007); catalogued as rs775525262, COSV58077724; called by muse, mutect2, varscan2
- IQCN | c.3419C>T p.A1140V | Missense Mutation (SNP) | VAF 36/337 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs200482859; called by muse, mutect2, varscan2
- IQCN | c.242G>A p.R81H | Missense Mutation (SNP) | VAF 29/204 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.044); catalogued as rs200448808; called by muse, mutect2, varscan2
- IQGAP3 | c.2563C>T p.R855C | Missense Mutation (SNP) | VAF 51/351 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs751001051, COSV63251278; called by muse, mutect2, varscan2
- IRAG1 | c.1685G>A p.R562H | Missense Mutation (SNP) | VAF 24/215 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs368966460, COSV70211482; called by muse, mutect2, varscan2
- IRF2BP1 | c.763C>T p.R255* | Nonsense Mutation (SNP) | VAF 72/534 reads (13%) | catalogued as COSV56195187; called by muse, mutect2, varscan2
- IRF3 | c.371C>T p.P124L | Missense Mutation (SNP) | VAF 18/230 reads (8%) | SIFT tolerated (0.23); PolyPhen benign (0.01); catalogued as rs1448585210; called by muse, mutect2
- IRX5 | c.545G>A p.R182Q | Missense Mutation (SNP) | VAF 58/429 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV58059176; called by muse, mutect2, varscan2
- ITGA2 | c.584dup p.L195Ffs*25 | Frame Shift Ins (INS) | VAF 40/335 reads (12%) | catalogued as rs1243641566; called by mutect2, pindel, varscan2
- ITGAX | c.1297G>A p.A433T | Missense Mutation (SNP) | VAF 17/119 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.331); catalogued as COSV51651946; called by muse, mutect2, varscan2
- ITIH4 | c.640C>T p.R214W | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.386); catalogued as rs754548083, COSV56579908; called by muse, mutect2, varscan2
- ITPR1 | c.55G>A p.A19T | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.994); catalogued as rs1319285632, COSV56983880; called by muse, mutect2, varscan2
- ITPR3 | c.6383G>A p.R2128Q | Missense Mutation (SNP) | VAF 39/330 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs907167572; called by muse, mutect2, varscan2
- JAKMIP1 | c.1543G>A p.A515T | Missense Mutation (SNP) | VAF 12/178 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.796); catalogued as rs1023704574, COSV51534944; called by muse, mutect2
- JARID2 | c.2357G>A p.R786Q | Missense Mutation (SNP) | VAF 30/240 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.153); catalogued as rs1371432770; called by muse, mutect2, varscan2
- JAZF1 | c.380C>T p.P127L | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.995); catalogued as rs1265343481, COSV52241098; called by muse, mutect2
- JHY | c.776dup p.N259Kfs*21 | Frame Shift Ins (INS) | VAF 18/172 reads (10%) | catalogued as rs756113544; called by mutect2, varscan2
- JPH1 | c.253dup p.E85Gfs*28 | Frame Shift Ins (INS) | VAF 21/145 reads (14%) | catalogued as rs1456517840; called by mutect2, pindel, varscan2
- KANSL1 | c.2309G>A p.R770H | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.997); catalogued as rs144377285; called by muse, mutect2
- KCNA2 | c.218G>A p.R73Q | Missense Mutation (SNP) | VAF 50/292 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs373042266; ClinVar: uncertain significance; called by muse, varscan2
- KCNA3 | c.842C>T p.T281M | Missense Mutation (SNP) | VAF 17/159 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.102); catalogued as COSV63900963; called by muse, mutect2, varscan2
- KCNA4 | c.646C>T p.R216C | Missense Mutation (SNP) | VAF 29/213 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.704); catalogued as rs768852661, COSV60251924, COSV60255631; called by muse, mutect2, varscan2
- KCNA5 | c.1780G>A p.V594M | Missense Mutation (SNP) | VAF 30/465 reads (6%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.039); catalogued as rs771488872, COSV52904153; called by muse, mutect2
- KCNB1 | c.2207G>A p.R736Q | Missense Mutation (SNP) | VAF 37/239 reads (15%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0); catalogued as rs151175979; called by muse, mutect2, varscan2
- KCNB1 | c.1724G>A p.R575H | Missense Mutation (SNP) | VAF 29/227 reads (13%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.007); catalogued as rs544069848, COSV65566363; called by muse, mutect2, varscan2
- KCNG1 | c.469G>A p.A157T | Missense Mutation (SNP) | VAF 28/212 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.22); catalogued as rs944101242, COSV65368054; called by muse, mutect2, varscan2
- KCNH1 | c.2603C>T p.A868V (on ENST00000271751 / NM_172362.3; = p.A841V on NM_002238.4) | Missense Mutation (SNP) | VAF 53/436 reads (12%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); catalogued as rs773735492, COSV55091075; called by muse, mutect2, varscan2
- KCNIP4 | c.106C>T p.R36W | Missense Mutation (SNP) | VAF 7/71 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as rs963531204; called by muse, mutect2, varscan2
- KCNJ4 | c.1087G>A p.A363T | Missense Mutation (SNP) | VAF 48/398 reads (12%) | SIFT tolerated (0.49); PolyPhen benign (0.011); catalogued as rs750382942, COSV57856856, COSV57856952; called by muse, mutect2, varscan2
- KCNJ4 | c.527C>T p.A176V | Missense Mutation (SNP) | VAF 48/298 reads (16%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.541); catalogued as rs1205735628, COSV57857987; called by muse, mutect2, varscan2
- KCNK4 | c.293G>A p.G98E | Missense Mutation (SNP) | VAF 7/71 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1184526408, COSV100107581, COSV60454319; called by muse, mutect2
- KCNN1 | c.773G>A p.R258H | Missense Mutation (SNP) | VAF 25/187 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV55837672; called by muse, mutect2, varscan2
- KCNS2 | c.1255C>T p.R419C | Missense Mutation (SNP) | VAF 46/382 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.586); catalogued as rs781697576, COSV54637693; called by muse, mutect2, varscan2
- KDM4E | c.886C>T p.R296* | Nonsense Mutation (SNP) | VAF 44/451 reads (10%) | catalogued as rs782730805; called by muse, mutect2
- KDM5D | c.3832C>T p.R1278C | Missense Mutation (SNP) | VAF 77/347 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs755094195; called by muse, mutect2, varscan2
- KIAA1109 | c.5302C>T p.R1768C | Missense Mutation (SNP) | VAF 9/91 reads (10%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.732); catalogued as COSV52667305; called by muse, mutect2, varscan2
- KIAA1109 | c.13123C>T p.R4375* | Nonsense Mutation (SNP) | VAF 17/118 reads (14%) | catalogued as rs1366683564, COSV99168197; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KIAA1143 | c.448G>A p.E150K | Missense Mutation (SNP) | VAF 14/107 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.086); catalogued as rs144499231; called by muse, mutect2
- KIAA1191 | c.448G>A p.E150K | Missense Mutation (SNP) | VAF 17/107 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.298); catalogued as rs749427721; called by muse, mutect2, varscan2
- KIAA1549L | c.3574G>A p.V1192M (on ENST00000321505; = p.V1489M on NM_012194.3) | Missense Mutation (SNP) | VAF 12/96 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1481006262, COSV55769803; called by muse, varscan2
- KIF18A | c.296G>A p.R99H | Missense Mutation (SNP) | VAF 19/162 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs565704097, COSV99588171; called by muse, mutect2, varscan2
- KIF1A | c.1240G>A p.A414T | Missense Mutation (SNP) | VAF 20/144 reads (14%) | SIFT tolerated (0.35); PolyPhen benign (0.043); catalogued as rs1345536541, COSV57483660; called by muse, mutect2, varscan2
- KIF26B | c.2116C>T p.R706C | Missense Mutation (SNP) | VAF 7/72 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs765715196, COSV63636090; called by muse, mutect2, varscan2
- KIFC1 | c.155G>A p.R52Q | Missense Mutation (SNP) | VAF 24/150 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.031); catalogued as rs750231969; called by muse, mutect2, varscan2
- KIRREL1 | c.332G>A p.R111Q | Missense Mutation (SNP) | VAF 15/134 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.435); catalogued as rs373857890; called by muse, mutect2, varscan2
- KLF15 | c.695C>T p.S232L | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.041); catalogued as rs762380089, COSV56180015; called by muse, mutect2, varscan2
- KLF4 | c.1108C>T p.P370S | Missense Mutation (SNP) | VAF 15/127 reads (12%) | SIFT tolerated (0.42); PolyPhen benign (0.006); catalogued as rs781545959; called by muse, mutect2, varscan2
- KLHDC7A | c.1471C>T p.R491C | Missense Mutation (SNP) | VAF 38/256 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as rs757074057; called by muse, mutect2, varscan2
- KLHDC7B | c.1294G>A p.A432T (on ENST00000395676; = p.A1073T on NM_138433.5) | Missense Mutation (SNP) | VAF 26/264 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs371425484; called by muse, mutect2
- KLHL23 | c.65del p.T23Qfs*9 | Frame Shift Del (DEL) | VAF 10/46 reads (22%) | catalogued as rs201368558; called by mutect2, varscan2
- KLHL26 | c.1016G>A p.R339H | Missense Mutation (SNP) | VAF 39/213 reads (18%) | SIFT tolerated (0.29); PolyPhen benign (0.056); catalogued as rs867504482; called by muse, mutect2, varscan2
- KLHL36 | c.1534G>A p.D512N | Missense Mutation (SNP) | VAF 40/357 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.515); catalogued as COSV50718743, COSV99257174; called by muse, mutect2, varscan2
- KLHL5 | c.263G>A p.R88Q | Missense Mutation (SNP) | VAF 22/242 reads (9%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as rs773124502; called by muse, mutect2
- KMT2B | c.5636del p.G1879Vfs*16 | Frame Shift Del (DEL) | VAF 56/446 reads (13%) | catalogued as COSV55868319; called by mutect2, varscan2
- KMT2B | c.6895C>T p.R2299W | Missense Mutation (SNP) | VAF 36/210 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as rs1247091755, COSV55858792; called by muse, mutect2, varscan2
- KPRP | c.1259C>T p.P420L | Missense Mutation (SNP) | VAF 30/304 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.138); catalogued as rs779553667, COSV64222995; called by muse, mutect2
- KRT14 | c.17G>A p.R6H | Missense Mutation (SNP) | VAF 39/243 reads (16%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.925); catalogued as rs760882737, CD064572; called by muse, mutect2, varscan2
- KRT28 | c.746C>T p.A249V | Missense Mutation (SNP) | VAF 18/149 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs775674491, COSV60686744; called by muse, mutect2, varscan2
- KRT33B | c.985C>T p.R329C | Missense Mutation (SNP) | VAF 38/409 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs766643158, COSV52440997; called by muse, mutect2
- KRT85 | c.278del p.P93Hfs*27 | Frame Shift Del (DEL) | VAF 49/403 reads (12%) | catalogued as rs762364040; called by mutect2, pindel, varscan2
- KRTAP19-1 | c.104G>A p.R35Q | Missense Mutation (SNP) | VAF 42/366 reads (11%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.007); catalogued as rs776685543, COSV66861066; called by muse, mutect2, varscan2
- KRTAP2-3 | c.179G>A p.R60H | Missense Mutation (SNP) | VAF 10/186 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as COSV101195309; called by muse, mutect2
- LAMA3 | c.5633G>A p.R1878H (on ENST00000313654 / NM_198129.4; = p.R269H on NM_000227.6) | Missense Mutation (SNP) | VAF 22/283 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.053); catalogued as rs746691398; called by muse, mutect2
- LAMB2 | c.4001G>A p.R1334Q | Missense Mutation (SNP) | VAF 84/721 reads (12%) | SIFT tolerated (0.38); PolyPhen benign (0.006); catalogued as rs144783830, COSV100026346; called by muse, mutect2, varscan2
- LAMB3 | c.2659C>T p.R887C | Missense Mutation (SNP) | VAF 80/675 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs368271817; called by muse, mutect2, varscan2
- LAMC3 | c.2354G>A p.R785H | Missense Mutation (SNP) | VAF 54/416 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); catalogued as rs752693131, COSV63092926; called by muse, mutect2, varscan2
- LARP1B | c.2257del p.M753Cfs*21 | Frame Shift Del (DEL) | VAF 7/48 reads (15%) | catalogued as rs1311334991; called by mutect2, pindel, varscan2
- LDB1 | c.472G>A p.D158N (on ENST00000425280 / NM_001321612.2; = p.D122N on NM_003893.5) | Missense Mutation (SNP) | VAF 20/191 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.069); catalogued as rs1392988031, COSV63289260; called by muse, mutect2, varscan2
- LDLRAD1 | c.104G>A p.R35H | Missense Mutation (SNP) | VAF 17/143 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.025); catalogued as rs892241900; called by muse, mutect2, varscan2
- LEF1 | c.1024C>T p.R342C | Missense Mutation (SNP) | VAF 8/97 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1445133819; called by muse, mutect2
- LEMD2 | c.930+1G>A p.X310_splice | Splice Site (SNP) | VAF 9/71 reads (13%) | catalogued as rs769401139, COSV53393167; called by muse, mutect2, varscan2
- LENG8 | c.907G>A p.A303T | Missense Mutation (SNP) | VAF 63/460 reads (14%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.67); catalogued as rs370057032; called by muse, mutect2, varscan2
- LGR4 | c.2449C>T p.R817* | Nonsense Mutation (SNP) | VAF 41/258 reads (16%) | catalogued as COSV60820482; called by muse, mutect2, varscan2
- LIG1 | c.2350G>A p.D784N | Missense Mutation (SNP) | VAF 16/196 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.384); catalogued as rs772420721; called by muse, mutect2
- LIMK2 | c.1557C>T p.N519= | Splice Region (SNP) | VAF 9/80 reads (11%) | catalogued as rs201696320, COSV100058460; called by mutect2, varscan2
- LIN37 | c.652C>T p.R218C | Missense Mutation (SNP) | VAF 67/594 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs757905028; called by muse, mutect2, varscan2
- LIPE | c.1925G>A p.R642H | Missense Mutation (SNP) | VAF 20/185 reads (11%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.991); catalogued as rs775624639, COSV54926224; called by muse, mutect2, varscan2
- LMAN2L | c.668C>T p.T223M | Missense Mutation (SNP) | VAF 35/266 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs375965191; called by muse, mutect2, varscan2
- LMOD3 | c.1394G>A p.R465H | Missense Mutation (SNP) | VAF 37/256 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs932535158, COSV70455648; called by muse, mutect2, varscan2
- LPA | c.3287C>T p.A1096V | Missense Mutation (SNP) | VAF 20/226 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.963); catalogued as rs375355500; called by muse, mutect2
- LPAR3 | c.139del p.S47Lfs*9 | Frame Shift Del (DEL) | VAF 20/142 reads (14%) | catalogued as rs762083435; called by mutect2, varscan2
- LRFN4 | c.901C>T p.R301W | Missense Mutation (SNP) | VAF 23/172 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs753688182; called by muse, mutect2, varscan2
- LRFN4 | c.1057G>A p.A353T | Missense Mutation (SNP) | VAF 30/205 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1245219655; called by muse, mutect2, varscan2
- LRP1 | c.10532G>A p.R3511H | Missense Mutation (SNP) | VAF 36/308 reads (12%) | SIFT tolerated (0.61); PolyPhen probably damaging (0.986); catalogued as COSV54518525; called by muse, varscan2
- LRP11 | c.874G>A p.V292M | Missense Mutation (SNP) | VAF 9/81 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs767503879, COSV53333357; called by mutect2, varscan2
- LRP11 | c.697G>A p.E233K | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.187); catalogued as rs11278; called by mutect2, varscan2
- LRRC15 | c.499G>A p.G167R | Missense Mutation (SNP) | VAF 48/424 reads (11%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.889); catalogued as rs762285932; called by mutect2, varscan2
- LRRC25 | c.544G>A p.A182T | Missense Mutation (SNP) | VAF 60/563 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.18); catalogued as rs1330516605; called by muse, mutect2, varscan2
- LRRC41 | c.400del p.S134Pfs*116 | Frame Shift Del (DEL) | VAF 11/85 reads (13%) | catalogued as rs1557715031, COSV58440688; called by mutect2, pindel, varscan2
- LRRC4B | c.719G>A p.R240Q | Missense Mutation (SNP) | VAF 25/190 reads (13%) | SIFT tolerated (0.45); PolyPhen benign (0.007); catalogued as rs1437238614; called by muse, mutect2, varscan2
- LRRC4B | c.235G>A p.E79K | Missense Mutation (SNP) | VAF 23/191 reads (12%) | SIFT tolerated (0.24); PolyPhen benign (0.067); catalogued as rs755494227; called by muse, mutect2, varscan2
- LSS | c.863C>T p.P288L | Missense Mutation (SNP) | VAF 17/148 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs769021391; called by muse, mutect2, varscan2
- LY75 | c.4235del p.K1412Rfs*2 | Frame Shift Del (DEL) | VAF 24/187 reads (13%) | catalogued as rs1301982151; called by mutect2, pindel, varscan2
- LYZL6 | c.337G>A p.A113T | Missense Mutation (SNP) | VAF 10/116 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.945); catalogued as rs771540627; called by muse, mutect2
- MACF1 | c.10004A>G p.E3335G | Missense Mutation (SNP) | VAF 14/86 reads (16%) | catalogued as rs1466066514; called by muse, mutect2, varscan2
- MAGEB1 | c.241G>A p.E81K | Missense Mutation (SNP) | VAF 32/148 reads (22%) | SIFT tolerated (0.35); PolyPhen benign (0.007); catalogued as rs754534422, COSV66775762; called by muse, mutect2, varscan2
- MAGEC1 | c.3339_3340del p.R1113Sfs*6 | Frame Shift Del (DEL) | VAF 15/88 reads (17%) | catalogued as rs754944988; called by pindel, varscan2
- MANEA | c.1243G>C p.V415L | Missense Mutation (SNP) | VAF 31/263 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.065); catalogued as rs763972020, COSV62590670; called by muse, mutect2, varscan2
- MAP3K1 | c.1240C>T p.R414C | Missense Mutation (SNP) | VAF 30/348 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs750675091; called by muse, mutect2
- MAP3K4 | c.479del p.N160Mfs*8 | Frame Shift Del (DEL) | VAF 15/132 reads (11%) | catalogued as COSV62334603; called by mutect2, varscan2
- MAP3K4 | c.2365G>A p.E789K | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs778740945; called by mutect2, varscan2
- MAP7D1 | c.1357G>A p.A453T | Missense Mutation (SNP) | VAF 17/114 reads (15%) | SIFT tolerated (0.27); PolyPhen benign (0.027); catalogued as rs778596898; called by muse, mutect2, varscan2
- MAPK3 | c.535G>A p.D179N | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53773960; called by muse, mutect2
- MAPK4 | c.609del p.N204Ifs*44 | Frame Shift Del (DEL) | VAF 12/115 reads (10%) | catalogued as COSV68541422; called by mutect2, pindel, varscan2
- MAPK8IP3 | c.1480C>T p.R494C | Missense Mutation (SNP) | VAF 39/225 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.276); catalogued as rs755666456, COSV51722872, COSV51727485; called by muse, mutect2, varscan2
- MARCHF4 | c.258del p.W87Gfs*72 | Frame Shift Del (DEL) | VAF 20/143 reads (14%) | catalogued as rs1559109946; called by mutect2, pindel, varscan2
- MARK1 | c.2164C>T p.R722* | Nonsense Mutation (SNP) | VAF 24/273 reads (9%) | catalogued as rs901442620, COSV100857114; called by muse, mutect2
- MARK2 | c.1162G>A p.A388T | Missense Mutation (SNP) | VAF 18/139 reads (13%) | SIFT tolerated (0.56); PolyPhen benign (0.019); catalogued as rs973521004, COSV59288594, COSV59289098; called by muse, mutect2, varscan2
- MARK4 | c.271G>A p.D91N | Missense Mutation (SNP) | VAF 21/164 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1443710354, COSV99488492; called by muse, mutect2, varscan2
- MARVELD3 | c.948dup p.Y317Vfs*22 | Frame Shift Ins (INS) | VAF 44/409 reads (11%) | catalogued as rs747980715; called by mutect2, varscan2
- MAST4 | c.3239C>T p.S1080L (on ENST00000403625 / NM_001164664.2; = p.S891L on NM_015183.3) | Missense Mutation (SNP) | VAF 34/311 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.127); catalogued as rs746331722; called by muse, mutect2, varscan2
- MATN2 | c.383G>A p.R128Q | Missense Mutation (SNP) | VAF 38/300 reads (13%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.595); catalogued as rs765585821; called by muse, mutect2, varscan2
- MBOAT7 | c.1243G>A p.V415M | Missense Mutation (SNP) | VAF 16/114 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.452); catalogued as rs35909464; called by muse, mutect2, varscan2
- MCF2L | c.579G>A p.P193= (on ENST00000375608; = p.P161= on NM_024979.4 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 14/156 reads (9%) | catalogued as rs758252641; called by muse, mutect2
- MCM9 | c.2890G>A p.A964T | Missense Mutation (SNP) | VAF 21/190 reads (11%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.031); catalogued as rs1275424147, COSV60325493; called by muse, mutect2, varscan2
- MDC1 | c.5798G>A p.R1933Q | Missense Mutation (SNP) | VAF 18/147 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs536243116, COSV64523145; called by muse, mutect2, varscan2
- MEAF6 | c.278C>T p.S93L | Missense Mutation (SNP) | VAF 13/88 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.087); catalogued as rs764216013, COSV56162906; called by muse, mutect2, varscan2
- MEAK7 | c.310G>A p.E104K | Missense Mutation (SNP) | VAF 22/223 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.645); catalogued as rs984673876, COSV59144569; called by muse, mutect2, varscan2
- MEGF11 | c.2113G>A p.A705T | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.764); catalogued as rs753342115; called by muse, mutect2, varscan2
- MEGF8 | c.7736C>T p.T2579M (on ENST00000251268 / NM_001271938.2; = p.T2512M on NM_001410.3) | Missense Mutation (SNP) | VAF 17/128 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs745623883; called by muse, mutect2, varscan2
- MEGF8 | c.8368G>A p.G2790R (on ENST00000251268 / NM_001271938.2; = p.G2723R on NM_001410.3) | Missense Mutation (SNP) | VAF 26/185 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs776276340, COSV52096959; called by muse, mutect2, varscan2
- MEOX1 | c.752C>T p.P251L | Missense Mutation (SNP) | VAF 18/105 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.056); catalogued as COSV100233782; called by muse, varscan2
- MEOX2 | c.791del p.K264Rfs*24 | Frame Shift Del (DEL) | VAF 37/353 reads (10%) | catalogued as COSV56293239; called by mutect2, pindel, varscan2
- MERTK | c.1449C>T p.H483= | Splice Region (SNP) | VAF 62/469 reads (13%) | catalogued as rs540628681, COSV54936090; called by muse, mutect2, varscan2
- MEX3B | c.1346C>T p.P449L | Missense Mutation (SNP) | VAF 11/109 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs747941977; called by mutect2, varscan2
- MFGE8 | c.923G>A p.R308H | Missense Mutation (SNP) | VAF 50/419 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs747199185; called by muse, mutect2, varscan2
- MIDEAS | c.607G>A p.A203T | Missense Mutation (SNP) | VAF 11/103 reads (11%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs368416534, COSV99678831; called by muse, mutect2, varscan2
- MINK1 | c.1562G>A p.R521Q | Missense Mutation (SNP) | VAF 39/285 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.078); catalogued as rs1414854670; called by muse, mutect2, varscan2
- MLF1 | c.79C>T p.R27* | Nonsense Mutation (SNP) | VAF 9/59 reads (15%) | catalogued as rs375897249; called by muse, mutect2, varscan2
- MLXIP | c.2266G>A p.A756T | Missense Mutation (SNP) | VAF 15/174 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs1291336415, COSV59835937; called by muse, mutect2
- MMP28 | c.455G>A p.R152Q | Missense Mutation (SNP) | VAF 48/421 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.727); catalogued as rs540834874; called by muse, mutect2, varscan2
- MOK | c.1182+6G>A | Splice Region (SNP) | VAF 48/319 reads (15%) | catalogued as rs1411609614; called by muse, mutect2, varscan2
- MRPL10 | c.120G>A p.M40I | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.505); catalogued as rs148416976; called by mutect2, varscan2
- MRPL3 | c.372A>G p.V124= | Splice Region (SNP) | VAF 16/126 reads (13%) | catalogued as rs774596618; called by muse, varscan2
- MRPL38 | c.1036C>T p.R346W | Missense Mutation (SNP) | VAF 13/83 reads (16%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.995); catalogued as rs745415254, COSV53932506; called by muse, mutect2, varscan2
- MRPS22 | c.563G>A p.R188Q (on ENST00000310776 / NM_001363893.1; = p.R189Q on NM_020191.4) | Missense Mutation (SNP) | VAF 30/248 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1192766845; called by muse, mutect2, varscan2
- MRTFA | c.1717G>A p.G573R | Missense Mutation (SNP) | VAF 47/408 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs202207258, COSV62935486; called by muse, mutect2, varscan2
- MSANTD3 | c.289G>A p.V97I | Missense Mutation (SNP) | VAF 30/270 reads (11%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs866386578; called by muse, mutect2, varscan2
- MSH5 | c.1562G>A p.R521Q | Missense Mutation (SNP) | VAF 14/146 reads (10%) | SIFT tolerated (0.45); PolyPhen benign (0.185); catalogued as rs1431554863; called by muse, mutect2
- MTMR10 | c.1708G>A p.V570M | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as rs747895020, COSV58727739; called by muse, mutect2, varscan2
- MUC19 | c.726C>T p.G242= | Splice Region (SNP) | VAF 10/90 reads (11%) | catalogued as rs61730701; called by muse, mutect2, varscan2
- MUC5B | c.5347C>T p.R1783C | Missense Mutation (SNP) | VAF 40/416 reads (10%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.547); catalogued as rs577818322; called by muse, mutect2
- MXRA7 | c.557C>T p.T186M | Missense Mutation (SNP) | VAF 13/91 reads (14%) | PolyPhen probably damaging (0.999); catalogued as rs1038906917, COSV63321189; called by muse, mutect2, varscan2
- MYBPC2 | c.2531G>A p.R844H | Missense Mutation (SNP) | VAF 25/245 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs377635463; called by muse, mutect2, varscan2
- MYCBP2 | c.8575A>G p.T2859A (on ENST00000357337; = p.T2897A on NM_015057.5) | Missense Mutation (SNP) | VAF 41/282 reads (15%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.931); catalogued as rs773154673; called by muse, mutect2, varscan2
- MYH13 | c.4006G>A p.A1336T | Missense Mutation (SNP) | VAF 8/123 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.686); catalogued as rs1461899559; called by muse, mutect2
- MYH14 | c.2784del p.R929Gfs*44 | Frame Shift Del (DEL) | VAF 26/182 reads (14%) | catalogued as COSV51828005; called by mutect2, varscan2
- MYH14 | c.4342G>A p.D1448N | Missense Mutation (SNP) | VAF 17/121 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1407925871, COSV51820024; called by muse, mutect2, varscan2
- MYH15 | c.1309G>A p.G437S | Missense Mutation (SNP) | VAF 14/101 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.74); catalogued as rs781328238, COSV99842624; called by muse, mutect2, varscan2
- MYH7B | c.3271_3273del p.K1091del | In Frame Del (DEL) | VAF 7/55 reads (13%) | catalogued as rs745416912; called by pindel, varscan2
- MYH9 | c.1915C>T p.R639W | Missense Mutation (SNP) | VAF 49/525 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99338498; called by muse, mutect2
- MYLK | c.1433G>A p.R478Q | Missense Mutation (SNP) | VAF 57/500 reads (11%) | SIFT tolerated (0.71); PolyPhen benign (0.012); catalogued as rs775483725, COSV100659895; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYO15A | c.3123del p.K1042Rfs*16 | Frame Shift Del (DEL) | VAF 26/274 reads (9%) | catalogued as rs769230097, COSV52762167; called by mutect2, pindel, varscan2
- MYO1A | c.455G>A p.R152H | Missense Mutation (SNP) | VAF 50/394 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs761072247, COSV55652192; called by muse, mutect2, varscan2
- MYO1C | c.134G>A p.R45Q (on ENST00000648651 / NM_001080779.2; = p.R10Q on NM_033375.5) | Missense Mutation (SNP) | VAF 36/337 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.426); catalogued as rs917030713; called by muse, mutect2, varscan2
- MYO1D | c.1865G>A p.R622H | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs569558606; called by muse, mutect2, varscan2
- MYO3B | c.2864G>A p.R955H | Missense Mutation (SNP) | VAF 27/172 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs770212469; called by muse, mutect2, varscan2
- MYO7A | c.2527G>A p.V843M | Missense Mutation (SNP) | VAF 38/266 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.247); catalogued as rs140559111; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- MYO7B | c.4766C>T p.A1589V | Missense Mutation (SNP) | VAF 22/256 reads (9%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs376500341; called by muse, mutect2
- N4BP1 | c.2002C>T p.R668C | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs377500906; called by muse, mutect2
- NACC1 | c.212C>T p.A71V | Missense Mutation (SNP) | VAF 28/198 reads (14%) | SIFT tolerated (0.26); PolyPhen benign (0.154); catalogued as rs779116546, COSV52835431; called by muse, mutect2, varscan2
- NAPSA | c.362G>A p.R121Q | Missense Mutation (SNP) | VAF 17/106 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs898399448, COSV53796589; called by muse, mutect2, varscan2
- NAV1 | c.1162G>A p.G388S | Missense Mutation (SNP) | VAF 27/216 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.05); catalogued as COSV55216549; called by muse, mutect2, varscan2
- NAV2 | c.55G>A p.G19R | Missense Mutation (SNP) | VAF 23/195 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); catalogued as rs1478456857, COSV62338307; called by muse, mutect2, varscan2
- NBEAL2 | c.1339C>T p.R447C | Missense Mutation (SNP) | VAF 37/262 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs1014720355; called by muse, mutect2, varscan2
- NBEAL2 | c.3827G>A p.R1276Q | Missense Mutation (SNP) | VAF 51/411 reads (12%) | SIFT tolerated (0.59); PolyPhen benign (0.048); catalogued as rs764506595, COSV99434474; called by muse, mutect2, varscan2
- NCAPH2 | c.898C>T p.R300W | Missense Mutation (SNP) | VAF 17/146 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); catalogued as rs558685651, COSV52686810; called by muse, mutect2, varscan2
- NDUFAF5 | c.311C>T p.A104V | Missense Mutation (SNP) | VAF 15/133 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.845); catalogued as rs749674610; called by muse, mutect2, varscan2
- NEIL1 | c.584G>A p.R195H | Missense Mutation (SNP) | VAF 46/323 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs140143535; called by muse, mutect2, varscan2
- NELFB | c.1777G>A p.G593S | Missense Mutation (SNP) | VAF 43/312 reads (14%) | SIFT tolerated (0.86); PolyPhen benign (0.014); catalogued as rs1414606352; called by muse, mutect2, varscan2
- NEPRO | c.577del p.R193Gfs*2 | Frame Shift Del (DEL) | VAF 13/114 reads (11%) | catalogued as rs757046366; called by mutect2, pindel, varscan2
- NFX1 | c.1600G>A p.G534S | Missense Mutation (SNP) | VAF 12/93 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.98); catalogued as rs752676329, COSV59309648; called by muse, mutect2, varscan2
- NFYA | c.844C>T p.R282* | Nonsense Mutation (SNP) | VAF 8/92 reads (9%) | catalogued as rs372824683; called by mutect2, varscan2
- NID1 | c.1060C>T p.Q354* | Nonsense Mutation (SNP) | VAF 22/173 reads (13%) | catalogued as COSV51622149; called by muse, mutect2, varscan2
- NKAPD1 | c.47G>A p.R16Q | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.544); catalogued as rs1183409958, COSV54774752; called by muse, mutect2
- NKD2 | c.343G>A p.D115N | Missense Mutation (SNP) | VAF 18/156 reads (12%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.557); catalogued as rs143957338; called by muse, mutect2, varscan2
- NKTR | c.2297del p.N766Ifs*30 | Frame Shift Del (DEL) | VAF 26/200 reads (13%) | catalogued as rs767007251; called by mutect2, varscan2
- NLGN4X | c.559G>A p.G187S | Missense Mutation (SNP) | VAF 23/124 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs766282731, COSV52014482; called by muse, mutect2, varscan2
- NLRC4 | c.1082C>T p.T361M | Missense Mutation (SNP) | VAF 24/215 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.029); catalogued as rs762565505; called by muse, mutect2, varscan2
- NLRP2 | c.1909G>A p.V637I | Missense Mutation (SNP) | VAF 30/352 reads (9%) | SIFT tolerated (0.47); PolyPhen benign (0.001); catalogued as rs558929398, COSV54758594; called by muse, mutect2
- NOP53 | c.712G>A p.V238M | Missense Mutation (SNP) | VAF 18/215 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.882); catalogued as rs756770937, COSV55881315; called by muse, mutect2
- NOS1 | c.1711G>A p.A571T | Missense Mutation (SNP) | VAF 20/122 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs368153115; called by muse, mutect2, varscan2
- NOS2 | c.3182G>A p.R1061Q | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (0.6); PolyPhen benign (0.028); catalogued as rs201995183, COSV58222037; called by mutect2, varscan2
- NOTCH1 | c.4583G>A p.C1528Y | Missense Mutation (SNP) | VAF 62/553 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53060149, COSV53062582; called by muse, mutect2, varscan2
- NOTCH3 | c.946G>A p.D316N | Missense Mutation (SNP) | VAF 70/524 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs200517339; called by muse, mutect2, varscan2
- NPC1 | c.2456G>A p.R819H | Missense Mutation (SNP) | VAF 32/258 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as rs751952669, COSV52579725; called by muse, mutect2, varscan2
- NPR2 | c.3064del p.D1022Mfs*4 | Frame Shift Del (DEL) | VAF 44/356 reads (12%) | catalogued as COSV52414032; called by mutect2, pindel, varscan2
- NR2C2AP | c.84del p.K28Nfs*22 | Frame Shift Del (DEL) | VAF 23/215 reads (11%) | catalogued as rs780246694; called by mutect2, pindel, varscan2
- NRDE2 | c.314C>T p.S105L | Missense Mutation (SNP) | VAF 25/203 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs371333350; called by muse, mutect2, varscan2
- NRP1 | c.1603C>T p.R535C | Missense Mutation (SNP) | VAF 56/420 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.581); catalogued as rs757164139; called by muse, mutect2, varscan2
- NRROS | c.371C>T p.T124M | Missense Mutation (SNP) | VAF 36/289 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.763); catalogued as rs762144741; called by muse, mutect2, varscan2
- NSD1 | c.2587G>A p.E863K | Missense Mutation (SNP) | VAF 24/204 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.881); catalogued as rs755866685; called by muse, mutect2, varscan2
- NSRP1 | c.1004G>A p.R335H | Missense Mutation (SNP) | VAF 13/100 reads (13%) | SIFT tolerated (0.33); PolyPhen benign (0.005); catalogued as rs770079774, COSV99898176; called by muse, mutect2, varscan2
- NSUN2 | c.1702C>T p.R568W | Missense Mutation (SNP) | VAF 10/91 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52956706; called by muse, mutect2, varscan2
- NT5DC2 | c.1381C>T p.R461C | Missense Mutation (SNP) | VAF 56/444 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100194768; called by muse, mutect2, varscan2
- NTHL1 | c.374dup p.V127Gfs*43 (on ENST00000219066; = p.V119Gfs*43 on NM_002528.7 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 14/93 reads (15%) | catalogued as rs763525759; called by mutect2, varscan2
- NTRK3 | c.1459G>A p.G487S | Missense Mutation (SNP) | VAF 32/386 reads (8%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.623); catalogued as rs750565995, COSV100448310, COSV58113168, COSV58150381; called by muse, mutect2
- NUP188 | c.2225C>T p.A742V | Missense Mutation (SNP) | VAF 33/283 reads (12%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.995); catalogued as rs148207291; called by muse, mutect2, varscan2
- NUP210 | c.4679G>A p.R1560H | Missense Mutation (SNP) | VAF 16/122 reads (13%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs766731599; called by muse, mutect2, varscan2
- NUP214 | c.4381G>A p.A1461T | Missense Mutation (SNP) | VAF 46/380 reads (12%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.015); catalogued as COSV63913732, COSV63914245; called by muse, mutect2, varscan2
- NUP42 | c.322G>A p.D108N | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs371807982; called by mutect2, varscan2
- NUP88 | c.2206C>T p.R736C | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs199908225; called by mutect2, varscan2
- NWD1 | c.727C>T p.R243C | Missense Mutation (SNP) | VAF 26/274 reads (9%) | SIFT tolerated (0.21); PolyPhen benign (0.01); catalogued as rs141437037; called by muse, mutect2
- OBSCN | c.13342C>T p.Q4448* | Nonsense Mutation (SNP) | VAF 18/171 reads (11%) | catalogued as COSV52816548; called by muse, mutect2, varscan2
- OLIG1 | c.314A>T p.Q105L | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.477); catalogued as rs1342362703, COSV60738293; called by muse, mutect2
- OPLAH | c.2512-6del | Splice Region (DEL) | VAF 41/336 reads (12%) | catalogued as rs782171361, COSV70679313; called by mutect2, varscan2
- OPRL1 | c.362C>T p.A121V | Missense Mutation (SNP) | VAF 41/341 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs767698847; called by muse, mutect2, varscan2
- OR10H5 | c.236C>T p.P79L | Missense Mutation (SNP) | VAF 24/153 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs370337382, COSV58279357; called by muse, mutect2, varscan2
- OR3A1 | c.394C>T p.P132S | Missense Mutation (SNP) | VAF 39/313 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.907); catalogued as rs1300024590; called by muse, mutect2, varscan2
- OR4C16 | c.89del p.L30Cfs*13 | Frame Shift Del (DEL) | VAF 18/152 reads (12%) | catalogued as rs752324980; called by mutect2, varscan2
- OR4F15 | c.547C>T p.R183W | Missense Mutation (SNP) | VAF 40/338 reads (12%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.192); catalogued as rs766043618, COSV59969453; called by muse, mutect2, varscan2
- OR51E2 | c.467del p.F156Sfs*6 | Frame Shift Del (DEL) | VAF 41/364 reads (11%) | catalogued as rs755413956; called by mutect2, varscan2
- OR51I1 | c.227C>T p.S76F | Missense Mutation (SNP) | VAF 52/455 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV66507628; called by muse, mutect2, varscan2
- OR52I1 | c.321del p.F107Lfs*4 | Frame Shift Del (DEL) | VAF 110/912 reads (12%) | catalogued as rs763340292; called by mutect2, varscan2
- OR6T1 | c.191G>A p.R64Q | Missense Mutation (SNP) | VAF 20/254 reads (8%) | SIFT tolerated (0.39); PolyPhen benign (0.015); catalogued as rs375228674; called by muse, mutect2
- OR8J3 | c.181T>C p.F61L | Missense Mutation (SNP) | VAF 20/224 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100041072, COSV56879215, COSV56883780; called by muse, mutect2
- ORAI1 | c.364G>A p.A122T | Missense Mutation (SNP) | VAF 32/303 reads (11%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.585); catalogued as rs1555324077; called by muse, mutect2, varscan2
- OSBPL10 | c.2216G>A p.R739H | Missense Mutation (SNP) | VAF 39/408 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.015); catalogued as rs764789997, COSV67335992; called by muse, mutect2, varscan2
- OSBPL2 | c.1228G>A p.G410S (on ENST00000313733 / NM_144498.4; = p.G398S on NM_014835.4) | Missense Mutation (SNP) | VAF 15/108 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.037); catalogued as rs143858748; called by muse, mutect2, varscan2
- OTOA | c.356G>A p.R119H | Missense Mutation (SNP) | VAF 28/298 reads (9%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as rs963348134; called by muse, mutect2
- OXCT2 | c.352G>A p.E118K | Missense Mutation (SNP) | VAF 18/133 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); catalogued as rs1397483750; called by mutect2, varscan2
- PABPC1L | c.1066C>T p.R356C | Missense Mutation (SNP) | VAF 34/411 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.062); catalogued as rs199499305; called by muse, mutect2
- PABPN1L | c.530C>T p.T177M | Missense Mutation (SNP) | VAF 33/380 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs990917750; called by muse, mutect2
- PACSIN3 | c.656G>A p.R219H | Missense Mutation (SNP) | VAF 24/118 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as rs549826440, COSV54065754; called by muse, mutect2, varscan2
- PAK3 | c.1676G>A p.R559H (on ENST00000262836 / NM_001324328.2; = p.R544H on NM_002578.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/117 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.976); catalogued as rs1251435916, COSV53276325, COSV99457053; called by muse, mutect2, varscan2
- PANX2 | c.443C>T p.T148M | Missense Mutation (SNP) | VAF 22/227 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); catalogued as COSV99348009; called by muse, mutect2, varscan2
- PAPOLG | c.697C>T p.R233C | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as rs775120420, COSV99475137; called by mutect2, varscan2
- PARD3 | c.425G>A p.R142H | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.932); catalogued as rs753692813, COSV60758090; called by muse, mutect2, varscan2
- PARD6A | c.266G>A p.R89H | Missense Mutation (SNP) | VAF 32/305 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1289906702, COSV54665961; called by muse, mutect2, varscan2
- PAX4 | c.179G>A p.R60H | Missense Mutation (SNP) | VAF 62/472 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs370095957; called by muse, mutect2, varscan2
- PAX6 | c.1124del p.P375Hfs*7 | Frame Shift Del (DEL) | VAF 34/358 reads (9%) | catalogued as CM011452; called by mutect2, pindel
- PCBP4 | c.775C>T p.R259C (on ENST00000322099 / NM_033010.2; = p.R216C on NM_020418.4) | Missense Mutation (SNP) | VAF 37/313 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs368578566; called by muse, mutect2, varscan2
- PCDH10 | c.2890C>T p.R964C | Missense Mutation (SNP) | VAF 26/276 reads (9%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.993); catalogued as rs376447518, COSV99993199, COSV99994076; called by muse, mutect2
- PCDH7 | c.1252C>T p.R418C | Missense Mutation (SNP) | VAF 22/187 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62341443; called by muse, mutect2, varscan2
- PCDHA1 | c.184C>T p.R62C | Missense Mutation (SNP) | VAF 40/339 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.786); catalogued as COSV65373470; called by muse, mutect2, varscan2
- PCDHA13 | c.1855C>T p.R619C | Missense Mutation (SNP) | VAF 64/560 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.849); catalogued as rs1360744073; called by muse, mutect2, varscan2
- PCDHA4 | c.2141C>T p.T714M | Missense Mutation (SNP) | VAF 44/476 reads (9%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.246); catalogued as COSV63538900; called by muse, mutect2
- PCDHB12 | c.101del p.L34Wfs*2 | Frame Shift Del (DEL) | VAF 8/80 reads (10%) | catalogued as rs781893572; called by mutect2, pindel, varscan2
- PCDHB2 | c.1714G>A p.A572T | Missense Mutation (SNP) | VAF 105/988 reads (11%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.109); catalogued as rs782442205; called by muse, varscan2
- PCDHGA12 | c.2731C>T p.R911W | Missense Mutation (SNP) | VAF 57/479 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as rs765756193, COSV52760559; called by muse, mutect2, varscan2
- PCM1 | c.2702_2704del p.E901del | In Frame Del (DEL) | VAF 12/104 reads (12%) | catalogued as rs757149191; called by pindel, varscan2
- PCNT | c.184G>A p.A62T | Missense Mutation (SNP) | VAF 40/386 reads (10%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs375098069, COSV52448967; called by muse, mutect2, varscan2
- PDCD1 | c.812C>A p.P271H | Missense Mutation (SNP) | VAF 46/299 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.615); catalogued as COSV100545567; called by muse, mutect2, varscan2
- PDCD1 | c.340C>T p.R114W | Missense Mutation (SNP) | VAF 44/321 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.882); catalogued as rs759277104, COSV100545507; called by muse, mutect2, varscan2
- PDE4A | c.2378C>T p.P793L (on ENST00000380702 / NM_001111307.2; = p.P554L on NM_006202.3) | Missense Mutation (SNP) | VAF 23/197 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs201230564; called by muse, mutect2, varscan2
- PDE4D | c.580C>T p.R194* (on ENST00000340635 / NM_001104631.2; = p.R58* on NM_006203.4) | Nonsense Mutation (SNP) | VAF 35/192 reads (18%) | catalogued as rs1488614653, COSV58961765; called by muse, mutect2, varscan2
- PDGFA | c.280G>A p.A94T | Missense Mutation (SNP) | VAF 23/156 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100627402; called by muse, mutect2, varscan2
- PDGFRB | c.1252C>T p.R418* | Nonsense Mutation (SNP) | VAF 11/97 reads (11%) | catalogued as rs1282693161, COSV55801662; called by muse, mutect2, varscan2
- PDHB | c.38G>A p.R13Q | Missense Mutation (SNP) | VAF 39/273 reads (14%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0); catalogued as rs202185395; called by muse, mutect2, varscan2
- PDIA2 | c.770G>A p.R257H | Missense Mutation (SNP) | VAF 52/362 reads (14%) | SIFT tolerated (0.51); PolyPhen benign (0.009); catalogued as rs369322100; called by muse, mutect2, varscan2
- PDZD7 | c.304C>T p.R102C | Missense Mutation (SNP) | VAF 70/580 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs766751821, COSV100931662; called by muse, mutect2, varscan2
- PEAK1 | c.3812C>T p.P1271L | Missense Mutation (SNP) | VAF 38/324 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.015); catalogued as rs1473546763; called by muse, mutect2, varscan2
- PEAK1 | c.2747G>A p.R916Q | Missense Mutation (SNP) | VAF 37/304 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.543); catalogued as rs749209617, COSV100432892; called by muse, mutect2, varscan2
- PELI3 | c.1000G>A p.V334M | Missense Mutation (SNP) | VAF 42/293 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1371494371, COSV57857556; called by muse, mutect2, varscan2
- PEX10 | c.437G>A p.R146H | Missense Mutation (SNP) | VAF 32/440 reads (7%) | SIFT tolerated (0.74); PolyPhen benign (0.011); catalogued as rs1471507257; called by muse, mutect2
- PEX11G | c.280G>A p.V94I | Missense Mutation (SNP) | VAF 13/87 reads (15%) | SIFT tolerated (0.24); PolyPhen benign (0.062); catalogued as rs772329624; called by muse, mutect2, varscan2
- PFDN2 | c.94C>T p.R32C | Missense Mutation (SNP) | VAF 19/199 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as rs761486495, COSV63510307; called by muse, mutect2, varscan2
- PFKFB3 | c.539C>T p.S180L | Missense Mutation (SNP) | VAF 19/171 reads (11%) | PolyPhen benign (0.277); catalogued as rs768274515; called by muse, varscan2
- PGAP2 | c.525+4C>T | Splice Region (SNP) | VAF 30/338 reads (9%) | catalogued as rs201840801; called by muse, mutect2
- PGAP3 | c.199G>A p.D67N | Missense Mutation (SNP) | VAF 15/106 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs201649387, COSV56132238; called by muse, mutect2, varscan2
- PGBD1 | c.2005del p.M669* | Frame Shift Del (DEL) | VAF 35/254 reads (14%) | catalogued as rs781166611; called by mutect2, pindel, varscan2
- PGBD4 | c.1064G>A p.R355H | Missense Mutation (SNP) | VAF 25/160 reads (16%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.892); catalogued as rs1430570302; called by muse, mutect2, varscan2
- PHC3 | c.2647C>T p.R883C (on ENST00000494943 / NM_001308116.2; = p.R895C on NM_024947.4) | Missense Mutation (SNP) | VAF 34/294 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs763467497, COSV71948948; called by muse, mutect2, varscan2
- PHEX | c.181G>A p.E61K | Missense Mutation (SNP) | VAF 26/112 reads (23%) | SIFT tolerated (0.83); PolyPhen possibly damaging (0.46); catalogued as rs770630990; called by muse, mutect2, varscan2
- PHF2 | c.1475del p.K492Rfs*6 | Frame Shift Del (DEL) | VAF 12/89 reads (13%) | catalogued as rs769717544; called by mutect2, varscan2
- PHF3 | c.5843G>A p.R1948H | Missense Mutation (SNP) | VAF 25/148 reads (17%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as rs371109942, COSV100013566; called by muse, mutect2, varscan2
- PI4KB | c.821G>A p.R274H (on ENST00000368873 / NM_001369623.1; = p.R286H on NM_002651.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/132 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs761617123, COSV55021204; called by muse, mutect2, varscan2
- PIDD1 | c.2219G>A p.R740Q | Missense Mutation (SNP) | VAF 62/423 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.886); catalogued as rs148849040; called by muse, mutect2, varscan2
- PIK3C2B | c.586G>A p.E196K | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0); catalogued as rs779068689; called by muse, mutect2, varscan2
- PIK3CG | c.1124G>A p.R375Q | Missense Mutation (SNP) | VAF 52/453 reads (11%) | SIFT tolerated (0.6); PolyPhen benign (0.037); catalogued as rs759982158, COSV63245875; called by muse, mutect2, varscan2
- PINK1 | c.857C>T p.P286L | Missense Mutation (SNP) | VAF 28/314 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs146691996; called by muse, mutect2
- PIP5K1C | c.568G>A p.V190I | Missense Mutation (SNP) | VAF 45/447 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.319); catalogued as rs1246673332; called by muse, mutect2
- PKD1 | c.10759G>A p.A3587T (on ENST00000262304 / NM_001009944.3; = p.A3586T on NM_000296.4) | Missense Mutation (SNP) | VAF 105/872 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.093); catalogued as rs1295445879; called by muse, mutect2, varscan2
- PKHD1 | c.4199C>T p.S1400L | Missense Mutation (SNP) | VAF 52/357 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.2); catalogued as rs191201723; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PKHD1 | c.2464G>A p.D822N | Missense Mutation (SNP) | VAF 45/435 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.9); catalogued as rs370436973; called by muse, mutect2, varscan2
- PKLR | c.1276C>T p.R426W | Missense Mutation (SNP) | VAF 94/685 reads (14%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.987); catalogued as rs1023689443, CM950955; called by muse, mutect2, varscan2
- PKP2 | c.1368del p.K456Nfs*3 | Frame Shift Del (DEL) | VAF 30/287 reads (10%) | catalogued as rs1393661338, CD061458; called by mutect2, pindel
- PLA2G12B | c.437G>A p.R146Q | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.251); catalogued as rs1012594473; called by muse, mutect2
- PLA2R1 | c.346C>T p.R116C | Missense Mutation (SNP) | VAF 32/208 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.446); catalogued as rs770554181; called by muse, mutect2, varscan2
- PLCL1 | c.1084C>G p.L362V | Missense Mutation (SNP) | VAF 20/238 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.062); catalogued as COSV104436643; called by muse, mutect2
- PLD1 | c.2749C>T p.R917C | Missense Mutation (SNP) | VAF 19/123 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774502670, COSV60573445; called by muse, mutect2, varscan2
- PLD2 | c.1571G>A p.R524Q | Missense Mutation (SNP) | VAF 31/191 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as rs769092786, COSV54003757; called by muse, mutect2, varscan2
- PLEC | c.8075C>T p.A2692V (on ENST00000322810 / NM_201380.4; = p.A2582V on NM_000445.5) | Missense Mutation (SNP) | VAF 70/750 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs1193397559; called by muse, mutect2
- PLEKHA4 | c.1762C>T p.R588W | Missense Mutation (SNP) | VAF 14/108 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.333); catalogued as rs377304447, COSV99612179; called by muse, mutect2
- PLEKHA4 | c.1499C>T p.P500L | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.105); catalogued as rs371447195; called by mutect2, varscan2
- PLEKHA6 | c.977G>A p.R326Q | Missense Mutation (SNP) | VAF 25/227 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs765347130, COSV55329570; called by muse, mutect2, varscan2
- PLEKHF1 | c.562C>T p.R188C | Missense Mutation (SNP) | VAF 18/216 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.935); catalogued as rs1428950199, COSV71410175; called by muse, mutect2
- PLEKHG4 | c.236C>T p.S79L | Missense Mutation (SNP) | VAF 46/423 reads (11%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.001); catalogued as rs760689398, COSV64611747; called by muse, mutect2, varscan2
- PLIN5 | c.338C>T p.T113M | Missense Mutation (SNP) | VAF 14/120 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.015); catalogued as rs201340592; called by muse, mutect2, varscan2
- PLXNA2 | c.163G>A p.V55I | Missense Mutation (SNP) | VAF 46/383 reads (12%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.816); catalogued as rs975879779, COSV65444068; called by muse, mutect2, varscan2
- PMEPA1 | c.111G>A p.T37= | Splice Region (SNP) | VAF 23/110 reads (21%) | catalogued as rs781430084; called by muse, mutect2, varscan2
- PMVK | c.233G>A p.R78H | Missense Mutation (SNP) | VAF 13/158 reads (8%) | SIFT tolerated (0.2); PolyPhen benign (0.005); catalogued as rs752708958; called by muse, mutect2
- PNKP | c.830C>T p.T277M | Missense Mutation (SNP) | VAF 82/677 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs1453288814, COSV55589066, COSV99681573; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- POFUT1 | c.1115C>T p.P372L | Missense Mutation (SNP) | VAF 26/148 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.089); catalogued as rs756587591; called by muse, mutect2, varscan2
- POLE | c.3857G>A p.R1286H | Missense Mutation (SNP) | VAF 29/249 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs771823596; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- POLQ | c.5545C>T p.R1849* | Nonsense Mutation (SNP) | VAF 13/123 reads (11%) | catalogued as rs746514158; called by muse, mutect2, varscan2
- POLQ | c.862C>T p.R288C | Missense Mutation (SNP) | VAF 23/143 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1372716245, COSV51763239; called by muse, mutect2, varscan2
- POMT2 | c.1577-8del | Splice Region (DEL) | VAF 41/301 reads (14%) | catalogued as rs749856419; ClinVar: likely benign; called by mutect2, pindel, varscan2
- POTEI | c.2182del p.R728Gfs*16 | Frame Shift Del (DEL) | VAF 41/303 reads (14%) | catalogued as rs775721804; called by mutect2, pindel, varscan2
- POU2F3 | c.278C>T p.P93L | Missense Mutation (SNP) | VAF 19/151 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.041); catalogued as rs199908870, COSV52792701; called by muse, mutect2, varscan2
- POU4F3 | c.185C>T p.A62V | Missense Mutation (SNP) | VAF 50/410 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.334); catalogued as rs912845369; called by muse, mutect2, varscan2
- PPARG | c.1446G>T p.Q482H (on ENST00000287820 / NM_015869.5; = p.Q452H on NM_005037.7) | Missense Mutation (SNP) | VAF 36/328 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.07); catalogued as COSV55146054; called by muse, mutect2, varscan2
- PPARGC1B | c.1288G>C p.E430Q | Missense Mutation (SNP) | VAF 30/241 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.081); catalogued as rs938838497, COSV58529685; called by muse, mutect2, varscan2
- PPCS | c.905G>A p.R302Q | Missense Mutation (SNP) | VAF 13/107 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as rs767257417; called by muse, mutect2, varscan2
- PPM1H | c.682C>T p.R228C | Missense Mutation (SNP) | VAF 16/140 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.075); catalogued as rs760993330, COSV104391347; called by muse, mutect2, varscan2
- PPP1R10 | c.930del p.V311Yfs*79 | Frame Shift Del (DEL) | VAF 21/176 reads (12%) | catalogued as rs746108087; called by mutect2, varscan2
1,616 further variants in this file (833 protein-altering or splice-affecting, 512 silent, 271 other) are not listed here.
